Somatic mutation profile of tumor specimen C3N-01877-04 (aliquot CPT0117510006) from CPTAC case C3N-01877, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage III; FIGO stage: Stage III; Tumor grade: G2; Age at diagnosis: 73.9 years (27,005 days).
Specimen C3N-01877-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4fb7d958-5e94-4847-8ad5-a74677597880.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01877-31 (Blood Derived Normal), aliquot CPT0117550002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a868ee78-ea49-456e-914c-25dec07c37d8

The open-access MAF lists 915 somatic variants for this specimen: 616 protein-altering or splice-affecting, 197 silent, 102 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 433, Silent 197, Frame Shift Del 105, Intron 53, Nonsense Mutation 29, Frame Shift Ins 27, RNA 15, 5'UTR 12, 3'UTR 10, Splice Site 9, Splice Region 8, 5'Flank 7.

Variants (750 of 915; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARSA | c.1115G>A p.R372Q | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs74315477, CM940108, COSV53350710, COSV53351367; ClinVar: pathogenic / uncertain significance; called by muse, mutect2
- B3GALT6 | c.588del p.R197Afs*81 | Frame Shift Del (DEL) | VAF 16/106 reads (15%) | catalogued as rs533071750, COSV55420617; ClinVar: pathogenic; called by mutect2, varscan2
- CEP290 | c.1606C>T p.Q536* | Nonsense Mutation (SNP) | VAF 12/110 reads (11%) | catalogued as rs1465414886, CM139097; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FGFR2 | c.755C>G p.S252W | Missense Mutation (SNP) | VAF 17/72 reads (24%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs79184941, CM950458, CM970526, COSV60638319; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- FLNB | c.1592del p.G531Dfs*42 | Frame Shift Del (DEL) | VAF 21/170 reads (12%) | catalogued as rs746105983; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PIK3CA | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 12/57 reads (21%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs121913287, CM126688, COSV55874568, COSV55924241; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.2816A>G p.D939G | Missense Mutation (SNP) | VAF 14/40 reads (35%) | hotspot (GDC flag); SIFT tolerated (0.83); PolyPhen benign (0.013); catalogued as COSV55911087; called by muse, mutect2, varscan2
- PPP2R1A | c.547C>T p.R183W | Missense Mutation (SNP) | VAF 24/176 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057519946, COSV59042187, COSV59042498; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.800del p.K267Rfs*9 | Frame Shift Del (DEL) | VAF 25/162 reads (15%) | catalogued as rs121913289; ClinVar: pathogenic; called by mutect2, varscan2
- PTEN | c.968dup p.N323Kfs*2 | Frame Shift Ins (INS) | VAF 12/83 reads (14%) | catalogued as rs121913291; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- ABCA7 | c.2617C>T p.R873C | Missense Mutation (SNP) | VAF 26/218 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.223); catalogued as rs767322746; called by muse, mutect2, varscan2
- ABCC5 | c.4207G>T p.G1403* | Nonsense Mutation (SNP) | VAF 8/106 reads (8%) | catalogued as COSV99657385; called by muse, mutect2
- ABT1 | c.691C>T p.R231C | Missense Mutation (SNP) | VAF 30/214 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.258); catalogued as rs782192030, COSV51291783; called by muse, mutect2, varscan2
- AC069544.2 | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 29/167 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.618); catalogued as rs1341356974; called by muse, mutect2, varscan2
- ACTR3B | c.1079C>T p.P360L | Missense Mutation (SNP) | VAF 43/227 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.567); catalogued as rs1245341628; called by muse, mutect2, varscan2
- ACTRT1 | c.467T>C p.V156A | Missense Mutation (SNP) | VAF 28/170 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.025); catalogued as COSV64419577; called by muse, mutect2, varscan2
- ACVRL1 | c.200G>T p.R67L | Missense Mutation (SNP) | VAF 64/372 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.44); catalogued as CM970042, COSV101187805, COSV66361103; called by muse, mutect2, varscan2
- ADAMTS16 | c.768G>A p.M256I | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV57007983, COSV99941601; called by muse, mutect2, varscan2
- ADRA2A | c.956G>A p.R319Q | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.46); PolyPhen benign (0.009); catalogued as rs1204711473; called by muse, varscan2
- AFAP1L1 | c.1862G>T p.R621M | Missense Mutation (SNP) | VAF 26/146 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); catalogued as rs1258569403; called by muse, mutect2, varscan2
- AGFG2 | c.443C>T p.P148L | Missense Mutation (SNP) | VAF 30/201 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs377262869, COSV53544837; called by muse, mutect2, varscan2
- ALG12 | c.771C>A p.T257= | Splice Region (SNP) | VAF 23/133 reads (17%) | catalogued as COSV58206501; called by muse, mutect2, varscan2
- ANK1 | c.97C>T p.R33W | Missense Mutation (SNP) | VAF 60/423 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.582); catalogued as rs1448156749, COSV99225369; called by muse, mutect2, varscan2
- ANKLE2 | c.587C>T p.P196L | Missense Mutation (SNP) | VAF 44/201 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.789); catalogued as rs754032001; called by muse, mutect2, varscan2
- ANKRD18B | c.853del p.R285Efs*4 | Frame Shift Del (DEL) | VAF 10/50 reads (20%) | catalogued as rs755445457; called by mutect2, varscan2
- ANKRD36B | c.1331C>T p.S444L | Missense Mutation (SNP) | VAF 18/183 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1356807816, COSV99308576; called by muse, mutect2, varscan2
- ANO10 | c.787C>T p.R263C | Missense Mutation (SNP) | VAF 24/145 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369488032; called by muse, mutect2, varscan2
- ANO5 | c.1747G>A p.V583I | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs375225649; called by muse, mutect2, varscan2
- AP4M1 | c.1034A>G p.Q345R | Missense Mutation (SNP) | VAF 68/427 reads (16%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.491); catalogued as COSV100384959; called by muse, mutect2, varscan2
- APC2 | c.3746G>A p.R1249H | Missense Mutation (SNP) | VAF 11/181 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs894952910, COSV52017448; ClinVar: uncertain significance; called by muse, mutect2
- APOB | c.11965C>T p.R3989C | Missense Mutation (SNP) | VAF 51/253 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.599); catalogued as rs150713761, COSV51926700; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARFGAP3 | c.647del p.K216Rfs*40 | Frame Shift Del (DEL) | VAF 5/49 reads (10%) | catalogued as rs1328173134; called by mutect2, pindel
- ARHGEF40 | c.3002G>A p.R1001Q | Missense Mutation (SNP) | VAF 40/225 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as rs780671481, COSV53878324; called by muse, mutect2, varscan2
- ARHGEF6 | c.1874C>T p.T625M | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.154); catalogued as rs774190321, COSV99166570; called by muse, mutect2, varscan2
- ARID1A | c.5010G>A p.W1670* | Nonsense Mutation (SNP) | VAF 25/147 reads (17%) | catalogued as COSV61379166; called by muse, mutect2, varscan2
- ARMC4 | c.820-8dup | Splice Region (INS) | VAF 6/50 reads (12%) | catalogued as rs775273884; called by mutect2, pindel
- ARPC5 | c.188del p.P63Lfs*9 | Frame Shift Del (DEL) | VAF 20/176 reads (11%) | catalogued as rs1558122795, COSV54172267; called by mutect2, pindel, varscan2
- ARPC5L | c.283C>T p.Q95* | Nonsense Mutation (SNP) | VAF 49/379 reads (13%) | catalogued as COSV52346927; called by muse, mutect2, varscan2
- ASB2 | c.599G>A p.R200H | Missense Mutation (SNP) | VAF 40/254 reads (16%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.63); catalogued as rs767336140, COSV60110275, COSV60112264; called by muse, mutect2, varscan2
- ATP2B2 | c.1120G>T p.V374L (on ENST00000352432; = p.V340L on NM_001683.5) | Missense Mutation (SNP) | VAF 39/237 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs150203000; called by muse, mutect2, varscan2
- BTK | c.1965G>A p.M655I | Missense Mutation (SNP) | VAF 19/140 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs782709592; called by muse, mutect2, varscan2
- CACNA1S | c.826G>A p.D276N | Missense Mutation (SNP) | VAF 86/731 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs757755172, COSV62937278; called by muse, mutect2, varscan2
- CACTIN | c.811G>A p.E271K | Missense Mutation (SNP) | VAF 68/363 reads (19%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.595); catalogued as rs1347230485; called by muse, mutect2, varscan2
- CAMSAP3 | c.790G>A p.A264T | Missense Mutation (SNP) | VAF 7/150 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV99349759; called by muse, mutect2
- CAPN10 | c.1326dup p.V443Rfs*18 | Frame Shift Ins (INS) | VAF 18/104 reads (17%) | catalogued as rs777656879; called by mutect2, pindel, varscan2
- CAPN2 | c.1435C>T p.P479S | Missense Mutation (SNP) | VAF 59/641 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.08); catalogued as COSV54337541; called by muse, mutect2
- CAVIN3 | c.186C>A p.S62R | Missense Mutation (SNP) | VAF 130/568 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.168); catalogued as rs777006937; called by muse, mutect2, varscan2
- CCAR1 | c.1678C>T p.R560C | Missense Mutation (SNP) | VAF 39/261 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs947218575, COSV56268736; called by muse, mutect2, varscan2
- CCDC88B | c.353del p.P118Qfs*61 | Frame Shift Del (DEL) | VAF 36/248 reads (15%) | catalogued as COSV57265375; called by mutect2, pindel, varscan2
- CCNB3 | c.2941G>A p.A981T | Missense Mutation (SNP) | VAF 43/232 reads (19%) | SIFT tolerated (0.62); PolyPhen benign (0.035); catalogued as rs782383616, COSV99330056; called by muse, mutect2, varscan2
- CDHR5 | c.1371del p.S458Pfs*47 (on ENST00000358353 / NM_001171968.2; = p.S458Pfs*53 on NM_021924.5) | Frame Shift Del (DEL) | VAF 12/81 reads (15%) | catalogued as rs1206877956; called by mutect2, pindel, varscan2
- CEP104 | c.844G>A p.E282K | Missense Mutation (SNP) | VAF 43/249 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs145723255; called by muse, mutect2, varscan2
- CEP68 | c.1091C>T p.A364V | Missense Mutation (SNP) | VAF 16/330 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as rs1276657961; called by muse, mutect2
- CFAP99 | c.296G>A p.G99D | Missense Mutation (SNP) | VAF 37/192 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868134189; called by muse, mutect2, varscan2
- CIT | c.5851C>T p.R1951* | Nonsense Mutation (SNP) | VAF 62/344 reads (18%) | catalogued as rs1304066853; called by muse, mutect2, varscan2
- CLPTM1 | c.1625G>A p.R542H | Missense Mutation (SNP) | VAF 39/262 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61612254; called by muse, mutect2, varscan2
- CLSTN3 | c.2858del p.P953Hfs*106 | Frame Shift Del (DEL) | VAF 5/34 reads (15%) | catalogued as rs758841384; called by mutect2, pindel, varscan2
- CNOT10 | c.658C>T p.Q220* | Nonsense Mutation (SNP) | VAF 4/16 reads (25%) | catalogued as rs201770145, COSV59390000; called by mutect2, varscan2
- COL4A1 | c.4528G>A p.V1510M | Missense Mutation (SNP) | VAF 40/284 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759921428, COSV65427793; called by muse, mutect2, varscan2
- CORO7 | c.1385C>T p.S462L | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as rs371031256; called by muse, mutect2, varscan2
- CR1L | c.668A>G p.Q223R | Missense Mutation (SNP) | VAF 74/615 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.313); catalogued as rs368142229; called by muse, mutect2, varscan2
- CRYBG3 | c.3485C>T p.A1162V | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.78); PolyPhen benign (0.012); catalogued as rs979517310; called by muse, mutect2, varscan2
- CSPP1 | c.2810G>A p.R937H (on ENST00000676605; = p.R896H on NM_024790.6) | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs375978348; called by muse, mutect2, varscan2
- CTNS | c.616G>A p.V206I | Missense Mutation (SNP) | VAF 83/481 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.081); catalogued as rs140572605, COSV50440844; called by muse, mutect2, varscan2
- CTSB | c.577G>A p.G193S | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.927); catalogued as rs371843229; called by muse, mutect2, varscan2
- DGKI | c.2705C>T p.A902V | Missense Mutation (SNP) | VAF 28/165 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as rs767812011, COSV55975220; called by muse, mutect2, varscan2
- DMD | c.7740G>T p.K2580N | Missense Mutation (SNP) | VAF 34/246 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.127); catalogued as COSV100629166; called by muse, mutect2, varscan2
- DNAH17 | c.9560C>T p.A3187V | Missense Mutation (SNP) | VAF 64/467 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs1285960422; called by muse, mutect2, varscan2
- DNAJC27 | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 26/147 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs770620180, COSV53095279; called by muse, mutect2, varscan2
- DOCK3 | c.994A>G p.T332A | Missense Mutation (SNP) | VAF 12/141 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs1279554942; called by muse, mutect2
- DOCK8 | c.3339del p.F1113Lfs*2 | Frame Shift Del (DEL) | VAF 20/129 reads (16%) | catalogued as rs748134881; called by mutect2, varscan2
- DSP | c.8198C>T p.T2733M | Missense Mutation (SNP) | VAF 9/213 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1561705229, COSV100672894; ClinVar: uncertain significance; called by muse, mutect2
- DTX3 | c.328G>A p.G110S | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.089); catalogued as rs1159978323; called by muse, mutect2
- EDAR | c.1309del p.V437Lfs*63 | Frame Shift Del (DEL) | VAF 30/146 reads (21%) | catalogued as rs1318702023; called by mutect2, pindel, varscan2
- EEF1AKMT4-ECE2 | c.2191C>T p.R731C | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs889995166, COSV62567748; called by muse, mutect2
- EFNB3 | c.13del p.H5Ifs*54 | Frame Shift Del (DEL) | VAF 7/42 reads (17%) | catalogued as rs745309220; called by mutect2, varscan2
- EIF4G3 | c.421del p.T141Lfs*2 | Frame Shift Del (DEL) | VAF 15/115 reads (13%) | catalogued as rs1290746509; called by mutect2, pindel, varscan2
- ELAVL1 | c.896C>T p.A299V | Missense Mutation (SNP) | VAF 36/219 reads (16%) | SIFT tolerated (0.5); PolyPhen benign (0.079); catalogued as COSV60965804; called by muse, mutect2, varscan2
- ELK4 | c.1001C>T p.T334M | Missense Mutation (SNP) | VAF 23/187 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs777039386; called by muse, mutect2, varscan2
- EMILIN2 | c.2890G>A p.A964T | Missense Mutation (SNP) | VAF 78/480 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.013); catalogued as rs765848472; called by muse, mutect2, varscan2
- ENC1 | c.970G>A p.A324T | Missense Mutation (SNP) | VAF 24/161 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.05); catalogued as rs769785953, COSV56631174; called by muse, mutect2, varscan2
- EPPK1 | c.4873G>A p.V1625M | Missense Mutation (SNP) | VAF 11/258 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs540029263; called by muse, mutect2
- ESPL1 | c.4054C>T p.R1352W | Missense Mutation (SNP) | VAF 25/218 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.628); catalogued as rs1312814330, COSV57758865; called by muse, mutect2, varscan2
- ESYT1 | c.1991G>A p.R664H | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.921); catalogued as rs763567977, COSV57275968; called by muse, varscan2
- FAM184B | c.2101C>T p.R701* | Nonsense Mutation (SNP) | VAF 13/261 reads (5%) | catalogued as rs1411435602, COSV99401784; called by muse, mutect2
- FAM81B | c.752C>T p.A251V | Missense Mutation (SNP) | VAF 28/154 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.23); catalogued as rs536458755; called by muse, mutect2, varscan2
- FANCA | c.3761_3762dup p.E1255Rfs*12 | Frame Shift Ins (INS) | VAF 24/164 reads (15%) | catalogued as rs868273545, CI032767; called by mutect2, varscan2
- FBN2 | c.6571G>A p.D2191N | Missense Mutation (SNP) | VAF 40/226 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.203); catalogued as rs1244642553, CM135273, COSV52491746; called by muse, mutect2, varscan2
- FCRLB | c.606G>T p.M202I | Missense Mutation (SNP) | VAF 25/160 reads (16%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV100396415; called by muse, mutect2, varscan2
- FGFR3 | c.749C>T p.P250L | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs4647924, CM022207, CM960655, COSV53402284, COSV53409935; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLG | c.10117C>T p.R3373C | Missense Mutation (SNP) | VAF 83/660 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs574781406, COSV100912444; called by muse, mutect2, varscan2
- FRY | c.7586C>T p.T2529I | Missense Mutation (SNP) | VAF 18/322 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.374); catalogued as rs1326658759; called by muse, mutect2
- GCNT4 | c.880dup p.H294Pfs*2 | Frame Shift Ins (INS) | VAF 14/78 reads (18%) | catalogued as rs768450027; called by mutect2, varscan2
- GDF5 | c.206C>G p.A69G | Missense Mutation (SNP) | VAF 49/263 reads (19%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as rs542574339; called by muse, mutect2, varscan2
- GFPT2 | c.1333G>A p.V445M | Missense Mutation (SNP) | VAF 49/293 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.337); catalogued as COSV53806643; called by muse, mutect2, varscan2
- GJC2 | c.922G>A p.A308T | Missense Mutation (SNP) | VAF 25/129 reads (19%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs1350981399; called by muse, mutect2, varscan2
- GPHN | c.1228C>T p.R410W (on ENST00000315266 / NM_001377519.1; = p.R443W on NM_020806.5) | Missense Mutation (SNP) | VAF 58/333 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); catalogued as rs376650247; called by muse, mutect2, varscan2
- H3C7 | c.142G>A p.A48T | Missense Mutation (SNP) | VAF 15/303 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.117); catalogued as COSV55101176; called by muse, mutect2
- H6PD | c.1729C>T p.R577* | Nonsense Mutation (SNP) | VAF 27/171 reads (16%) | catalogued as rs760218420; called by muse, mutect2, varscan2
- HLX | c.656C>T p.S219L | Missense Mutation (SNP) | VAF 29/187 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.229); catalogued as rs751088009, COSV65045195, COSV65045833; called by muse, mutect2, varscan2
- HNRNPUL2 | c.1423G>T p.E475* | Nonsense Mutation (SNP) | VAF 22/163 reads (13%) | catalogued as COSV57131146; called by muse, varscan2
- HOXA3 | c.656C>T p.P219L | Missense Mutation (SNP) | VAF 37/253 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.7); catalogued as rs1381290384, COSV57827313; called by muse, mutect2, varscan2
- HSPA4L | c.1722del p.G575Efs*18 | Frame Shift Del (DEL) | VAF 14/62 reads (23%) | catalogued as rs775794446; called by mutect2, pindel
- IGLV3-21 | c.113G>T p.R38M | Missense Mutation (SNP) | VAF 47/248 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.131); catalogued as rs749809974; called by muse, mutect2, varscan2
- IL17F | c.143C>T p.P48L | Missense Mutation (SNP) | VAF 60/407 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1390182393; called by muse, mutect2, varscan2
- IL17RD | c.1384C>T p.R462C | Missense Mutation (SNP) | VAF 27/140 reads (19%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.861); catalogued as rs775773650, COSV56337327; called by muse, mutect2, varscan2
- INPPL1 | c.1555G>A p.E519K | Missense Mutation (SNP) | VAF 39/233 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.443); catalogued as rs1420082156; called by muse, mutect2, varscan2
- INTS1 | c.3287G>A p.R1096H | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767739805, COSV99081248; called by muse, mutect2, varscan2
- IPO4 | c.2534C>T p.A845V | Missense Mutation (SNP) | VAF 35/263 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.317); catalogued as rs773268677, COSV61015093; called by muse, mutect2, varscan2
- IRX5 | c.805dup p.R269Pfs*187 | Frame Shift Ins (INS) | VAF 41/192 reads (21%) | catalogued as rs754238323; called by mutect2, varscan2
- ITGA9 | c.2419A>G p.N807D | Missense Mutation (SNP) | VAF 41/294 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.826); catalogued as rs1243507939; called by muse, mutect2, varscan2
- ITGB2 | c.1579T>A p.S527T (on ENST00000302347; = p.S503T on NM_000211.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 81/501 reads (16%) | SIFT tolerated (0.53); PolyPhen benign (0.009); catalogued as rs1568882038; called by muse, mutect2, varscan2
- JAK1 | c.3109G>A p.V1037I | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53807048; called by muse, mutect2
- KAT2A | c.2122G>A p.V708I | Missense Mutation (SNP) | VAF 35/195 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1347629766, COSV52424926; called by muse, mutect2, varscan2
- KAT6A | c.4352C>T p.A1451V | Missense Mutation (SNP) | VAF 13/122 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.842); catalogued as rs148148486; called by muse, mutect2, varscan2
- KCNK12 | c.19del p.R7Gfs*124 | Frame Shift Del (DEL) | VAF 8/80 reads (10%) | catalogued as rs1166720095; called by mutect2, pindel
- KDM5C | c.3719C>T p.T1240I | Missense Mutation (SNP) | VAF 16/359 reads (4%) | SIFT tolerated (0.31); PolyPhen benign (0.146); catalogued as rs782020999; called by muse, mutect2
- KDM7A | c.2812C>T p.R938C | Missense Mutation (SNP) | VAF 24/127 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.959); catalogued as rs780860802, COSV50096000; called by muse, mutect2, varscan2
- KIF26B | c.2660del p.P887Qfs*35 | Frame Shift Del (DEL) | VAF 23/237 reads (10%) | catalogued as rs1208357637; called by mutect2, pindel, varscan2
- KLHL14 | c.745G>A p.D249N | Missense Mutation (SNP) | VAF 28/129 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs766608452; called by muse, mutect2, varscan2
- KRT6B | c.710C>T p.S237L | Missense Mutation (SNP) | VAF 133/692 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.17); catalogued as rs764052533, COSV52883501; called by muse, mutect2, varscan2
- KRT72 | c.157G>A p.G53R | Missense Mutation (SNP) | VAF 33/630 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.025); catalogued as rs532136578; called by muse, mutect2
- LAMA3 | c.3979C>T p.R1327C | Missense Mutation (SNP) | VAF 59/364 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.498); catalogued as rs367562646; called by muse, mutect2, varscan2
- LARP4 | c.2090G>A p.R697H | Missense Mutation (SNP) | VAF 53/268 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.944); catalogued as rs1259798490; called by muse, mutect2, varscan2
- LHX1 | c.902C>T p.P301L | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs148800710; called by muse, mutect2, varscan2
- LPCAT3 | c.1234G>A p.A412T | Missense Mutation (SNP) | VAF 34/216 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as rs782041747; called by muse, mutect2, varscan2
- LRP1 | c.4766G>A p.R1589H | Missense Mutation (SNP) | VAF 50/257 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54511336, COSV54519443; called by muse, mutect2, varscan2
- LRRK2 | c.4000C>T p.R1334* | Nonsense Mutation (SNP) | VAF 16/72 reads (22%) | catalogued as rs201177073, CM125635; called by muse, mutect2, varscan2
- LRRN1 | c.1786C>T p.L596F | Missense Mutation (SNP) | VAF 31/156 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60012519; called by muse, mutect2, varscan2
- LUC7L2 | c.934C>T p.R312C | Missense Mutation (SNP) | VAF 26/308 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as rs778100107; called by muse, mutect2
- LUZP1 | c.2246C>T p.A749V | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as rs1244632424, COSV56505006; called by muse, mutect2, varscan2
- MAGEE1 | c.947C>T p.S316L | Missense Mutation (SNP) | VAF 49/264 reads (19%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as rs1569336299, COSV63908898; called by muse, mutect2, varscan2
- MAOB | c.389C>T p.P130L | Missense Mutation (SNP) | VAF 36/207 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.567); catalogued as rs17852046; called by muse, mutect2, varscan2
- MAP3K3 | c.1528G>A p.A510T | Missense Mutation (SNP) | VAF 34/284 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV51991396; called by muse, mutect2, varscan2
- MASP2 | c.166C>T p.R56C | Missense Mutation (SNP) | VAF 46/265 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs927426521, COSV68896475; called by muse, mutect2, varscan2
- MEFV | c.1477C>T p.Q493* | Nonsense Mutation (SNP) | VAF 114/574 reads (20%) | catalogued as rs770738099; called by muse, mutect2, varscan2
- MFSD9 | c.1326del p.S443Afs*6 | Frame Shift Del (DEL) | VAF 19/107 reads (18%) | catalogued as rs769987847; called by mutect2, pindel, varscan2
- MIOS | c.616C>T p.R206C | Missense Mutation (SNP) | VAF 21/174 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs1428064398, COSV60770926; called by muse, mutect2, varscan2
- MRAP2 | c.186dup p.V63Cfs*40 | Frame Shift Ins (INS) | VAF 28/194 reads (14%) | catalogued as rs758625941; called by mutect2, pindel, varscan2
- MS4A14 | c.1933G>T p.E645* | Nonsense Mutation (SNP) | VAF 26/213 reads (12%) | catalogued as COSV100280114; called by muse, mutect2, varscan2
- MUC2 | c.614C>T p.T205M | Missense Mutation (SNP) | VAF 21/137 reads (15%) | SIFT deleterious (0.04); catalogued as rs567487148; called by muse, mutect2, varscan2
- MYBL2 | c.1199del p.G400Afs*58 | Frame Shift Del (DEL) | VAF 15/134 reads (11%) | catalogued as COSV53831694; called by mutect2, varscan2
- MYCN | c.1204C>T p.L402F | Missense Mutation (SNP) | VAF 100/547 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.346); catalogued as COSV55258238; called by muse, mutect2, varscan2
- MYO9B | c.3865G>A p.D1289N | Missense Mutation (SNP) | VAF 37/718 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.065); catalogued as rs370235281; called by muse, mutect2
- MYOM3 | c.49dup p.Q17Pfs*43 | Frame Shift Ins (INS) | VAF 22/100 reads (22%) | catalogued as rs532144295; called by mutect2, varscan2
- MYORG | c.700G>A p.A234T | Missense Mutation (SNP) | VAF 50/417 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as rs1411767427, COSV99898244; called by muse, mutect2, varscan2
- NAV2 | c.2306del p.G769Efs*21 (on ENST00000396087 / NM_001244963.2; = p.G746Efs*21 on NM_145117.5) | Frame Shift Del (DEL) | VAF 22/137 reads (16%) | catalogued as COSV100584900; called by mutect2, pindel, varscan2
- NBEA | c.3229T>A p.S1077T | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.003); catalogued as rs757170136; called by muse, mutect2, varscan2
- NBPF9 | c.665A>G p.Q222R | Missense Mutation (SNP) | VAF 64/607 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as rs1553654708; called by muse, mutect2, varscan2
- NCOR2 | c.4367C>T p.P1456L | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs865996390; called by muse, mutect2, varscan2
- NCOR2 | c.4172G>A p.R1391Q | Missense Mutation (SNP) | VAF 29/174 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs1374909069; called by muse, mutect2, varscan2
- NHSL2 | c.319A>G p.K107E (on ENST00000510661; = p.K473E on NM_001013627.2) | Missense Mutation (SNP) | VAF 37/206 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs749731637; called by muse, mutect2, varscan2
- NID1 | c.2639C>T p.A880V | Missense Mutation (SNP) | VAF 40/437 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as rs911258804, COSV51618656; called by muse, mutect2
- NLRP3 | c.424G>A p.V142M | Missense Mutation (SNP) | VAF 35/367 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.475); catalogued as rs1284696978, COSV100276704; called by muse, mutect2, varscan2
- NMRAL1 | c.220G>A p.A74T | Missense Mutation (SNP) | VAF 37/268 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.464); catalogued as rs745424104, COSV52060585; called by muse, mutect2, varscan2
- NOL11 | c.1297A>G p.I433V | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV99036774; called by muse, mutect2
- NOSTRIN | c.1452dup p.G485Rfs*57 (on ENST00000317647 / NM_001039724.4; = p.G407Rfs*? on NM_052946.3) | Frame Shift Ins (INS) | VAF 21/147 reads (14%) | catalogued as rs757832201; called by mutect2, pindel, varscan2
- NPAT | c.2786-3del | Splice Region (DEL) | VAF 23/132 reads (17%) | catalogued as rs35747263; called by mutect2, varscan2
- NRIP1 | c.2184del p.E729Rfs*5 | Frame Shift Del (DEL) | VAF 14/78 reads (18%) | catalogued as rs776154715; called by mutect2, varscan2
- NUP205 | c.3179C>T p.A1060V | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.426); catalogued as COSV99606545; called by muse, mutect2, varscan2
- OBSL1 | c.4294C>T p.R1432W | Missense Mutation (SNP) | VAF 42/199 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs774564230; called by muse, mutect2, varscan2
- OR2T3 | c.275C>T p.T92I | Missense Mutation (SNP) | VAF 20/398 reads (5%) | SIFT tolerated (0.45); PolyPhen benign (0.091); catalogued as COSV100613417; called by muse, mutect2
- OR4D5 | c.811G>A p.V271I | Missense Mutation (SNP) | VAF 43/207 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0.05); catalogued as rs564572858, COSV58305578; called by muse, mutect2, varscan2
- OR5W2 | c.875T>C p.L292P | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60617325; called by muse, mutect2, varscan2
- OTOG | c.1928G>A p.R643Q | Missense Mutation (SNP) | VAF 40/249 reads (16%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.987); catalogued as rs541019060; called by muse, mutect2, varscan2
- PANX1 | c.455G>A p.R152H | Missense Mutation (SNP) | VAF 42/239 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs572944224, COSV57133165; called by muse, mutect2, varscan2
- PAPPA | c.4567C>T p.R1523C | Missense Mutation (SNP) | VAF 25/224 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.528); catalogued as rs887198926; called by muse, mutect2, varscan2
- PAPPA2 | c.5055del p.S1686Vfs*4 | Frame Shift Del (DEL) | VAF 26/235 reads (11%) | catalogued as rs747970462, COSV62809272; called by mutect2, pindel, varscan2
- PAQR8 | c.62G>A p.R21H | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.864); catalogued as rs772469249; called by muse, mutect2, varscan2
- PAWR | c.162dup p.A55Rfs*72 | Frame Shift Ins (INS) | VAF 11/78 reads (14%) | catalogued as rs1332724929; called by mutect2, pindel, varscan2
- PAX6 | c.17G>A p.S6N | Missense Mutation (SNP) | VAF 33/241 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV53792443; called by muse, mutect2, varscan2
- PCDHB7 | c.1966G>A p.A656T | Missense Mutation (SNP) | VAF 82/1684 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.023); catalogued as rs782388523, COSV50763014; called by muse, mutect2
- PCDHGA8 | c.289G>A p.A97T | Missense Mutation (SNP) | VAF 23/187 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.26); catalogued as COSV53977121; called by muse, mutect2, varscan2
- PCDHGB7 | c.1622C>T p.A541V | Missense Mutation (SNP) | VAF 88/451 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.473); catalogued as COSV53914746; called by muse, mutect2, varscan2
- PDGFRA | c.1295C>T p.T432M | Missense Mutation (SNP) | VAF 47/213 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.033); catalogued as rs750809787, COSV57270086; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PGR | c.352_353del p.L118Vfs*65 | Frame Shift Del (DEL) | VAF 48/351 reads (14%) | catalogued as rs777896116; called by pindel, varscan2
- PHACTR2 | c.685del p.T229Qfs*47 | Frame Shift Del (DEL) | VAF 15/77 reads (19%) | catalogued as rs746858891; called by mutect2, varscan2
- PHKB | c.2579T>A p.I860N | Missense Mutation (SNP) | VAF 31/192 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as rs1332599193; called by muse, mutect2, varscan2
- PHYHIP | c.320C>T p.T107M | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.343); catalogued as rs758356973, COSV100395070; called by muse, mutect2, varscan2
- PLEKHG4B | c.658C>T p.R220C (on ENST00000283426; = p.R576C on NM_052909.5) | Missense Mutation (SNP) | VAF 35/209 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs149661863, COSV52052280; called by muse, mutect2, varscan2
- PLXNA3 | c.3701C>T p.A1234V | Missense Mutation (SNP) | VAF 22/312 reads (7%) | SIFT tolerated (0.5); PolyPhen benign (0.021); catalogued as rs1557207895; called by muse, mutect2
- PPP6C | c.331C>T p.R111* | Nonsense Mutation (SNP) | VAF 12/83 reads (14%) | catalogued as rs761088509, COSV65208029, COSV65208447; called by muse, mutect2, varscan2
- PRG4 | c.1994C>T p.A665V | Missense Mutation (SNP) | VAF 24/156 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV63355765; called by muse, varscan2
- PRKD3 | c.539G>A p.R180H | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52216192; called by muse, mutect2, varscan2
- PRLR | c.1134G>T p.E378D | Missense Mutation (SNP) | VAF 54/303 reads (18%) | SIFT tolerated (0.56); PolyPhen benign (0.018); catalogued as rs764694626; called by muse, mutect2, varscan2
- PTGER4 | c.784C>T p.R262C | Missense Mutation (SNP) | VAF 15/187 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs1249918246, COSV100201428; called by muse, mutect2
- PTPN21 | c.2207G>A p.R736Q | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.031); catalogued as rs1239536771, COSV100161529; called by muse, mutect2
- PTPRCAP | c.274C>T p.Q92* | Nonsense Mutation (SNP) | VAF 10/204 reads (5%) | catalogued as rs1176313412; called by muse, mutect2
- PTPRN | c.1897C>T p.R633C | Missense Mutation (SNP) | VAF 48/240 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs145776595; called by muse, mutect2, varscan2
- QSER1 | c.5090del p.N1697Mfs*4 (on ENST00000399302; = p.N1826Mfs*4 on NM_001076786.3) | Frame Shift Del (DEL) | VAF 6/38 reads (16%) | catalogued as rs754588466; called by mutect2, varscan2
- RCAN3 | c.488C>T p.A163V | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as rs764690503, COSV65558151; called by muse, mutect2, varscan2
- RFESD | c.326A>G p.K109R | Missense Mutation (SNP) | VAF 32/196 reads (16%) | SIFT tolerated (0.5); PolyPhen benign (0.006); catalogued as rs1252777964; called by muse, varscan2
- RGPD3 | c.283G>T p.D95Y | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100450748; called by muse, mutect2, varscan2
- RHBDF2 | c.2075G>A p.R692H | Missense Mutation (SNP) | VAF 33/228 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as rs754066543, COSV51684954; called by muse, mutect2, varscan2
- RHBDL3 | c.1084G>A p.E362K | Missense Mutation (SNP) | VAF 92/491 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs199506478; called by muse, mutect2, varscan2
- RLN1 | c.479del p.K160Rfs*14 | Frame Shift Del (DEL) | VAF 20/111 reads (18%) | catalogued as rs758351039; called by mutect2, pindel, varscan2
- ROBO2 | c.3233dup p.V1079Sfs*22 | Frame Shift Ins (INS) | VAF 24/100 reads (24%) | catalogued as rs745519558; called by mutect2, varscan2
- ROBO3 | c.256C>T p.R86C | Missense Mutation (SNP) | VAF 50/273 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV67300665; called by muse, mutect2, varscan2
- ROBO3 | c.571del p.R191Afs*31 | Frame Shift Del (DEL) | VAF 26/163 reads (16%) | catalogued as rs756837590; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- RPS9 | c.570C>G p.D190E | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs142681896, COSV57190636; called by muse, varscan2
- RYR2 | c.14253G>T p.K4751N | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63700454; called by muse, varscan2
- SCML1 | c.635G>A p.G212D (on ENST00000380041 / NM_001037540.3; = p.G185D on NM_006746.6) | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.146); catalogued as rs1257758703; called by muse, mutect2, varscan2
- SDF4 | c.502_504del p.K168del | In Frame Del (DEL) | VAF 20/170 reads (12%) | catalogued as rs756891917; called by mutect2, pindel
- SDK1 | c.587C>T p.T196M | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.01); catalogued as rs755048901, COSV67378774; called by muse, mutect2, varscan2
- SEC31A | c.1384del p.I462Lfs*16 | Frame Shift Del (DEL) | VAF 27/146 reads (18%) | catalogued as rs748463349, COSV52348607; called by mutect2, varscan2
- SECISBP2L | c.566C>A p.P189Q | Missense Mutation (SNP) | VAF 18/183 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs762754299, COSV55932479, COSV55937125; called by muse, mutect2, varscan2
- SELENON | c.455G>A p.S152N | Missense Mutation (SNP) | VAF 74/352 reads (21%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs762382665; called by muse, mutect2, varscan2
- SEMA6A | c.2542G>A p.A848T | Missense Mutation (SNP) | VAF 78/463 reads (17%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.793); catalogued as rs754006049; called by muse, mutect2, varscan2
- SETD3 | c.466G>A p.A156T | Missense Mutation (SNP) | VAF 23/162 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs745547818, COSV59286748; called by muse, mutect2, varscan2
- SGCE | c.63del p.T22Hfs*4 | Frame Shift Del (DEL) | VAF 47/292 reads (16%) | catalogued as rs760824608; called by mutect2, pindel, varscan2
- SH3TC1 | c.370C>T p.L124F | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT tolerated (0.76); PolyPhen benign (0.014); catalogued as rs1437682914; called by muse, mutect2
- SLC22A23 | c.1038G>T p.Q346H | Missense Mutation (SNP) | VAF 27/186 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100977797; called by muse, mutect2, varscan2
- SLC23A1 | c.95_97del p.L32del | In Frame Del (DEL) | VAF 13/99 reads (13%) | catalogued as rs765797895; called by pindel, varscan2
- SLC23A3 | c.611C>T p.A204V | Missense Mutation (SNP) | VAF 16/286 reads (6%) | SIFT tolerated (0.33); PolyPhen benign (0.047); catalogued as rs1189310212; called by muse, mutect2
- SLC26A7 | c.58del p.Q20Sfs*24 | Frame Shift Del (DEL) | VAF 14/67 reads (21%) | catalogued as rs749030792; called by mutect2, pindel, varscan2
- SLIT1 | c.4384del p.D1462Tfs*42 | Frame Shift Del (DEL) | VAF 22/130 reads (17%) | catalogued as COSV56588958; called by mutect2, pindel, varscan2
- SMG5 | c.2027C>T p.A676V | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.84); catalogued as rs1412823006, COSV62435592; called by muse, mutect2
- SND1 | c.1906C>T p.R636C | Missense Mutation (SNP) | VAF 23/220 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100691099; called by muse, mutect2, varscan2
- SOX9 | c.66del p.S23Afs*38 | Frame Shift Del (DEL) | VAF 16/89 reads (18%) | catalogued as COSV55428538; called by mutect2, pindel, varscan2
- SPDYC | c.868C>T p.R290C | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs552653826, COSV65865069; called by muse, mutect2, varscan2
- SPSB4 | c.280G>A p.A94T | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1421070243, COSV60148171; called by muse, mutect2, varscan2
- SPTLC3 | c.35G>A p.G12E | Missense Mutation (SNP) | VAF 29/202 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.025); catalogued as rs1432253087; called by muse, mutect2, varscan2
- STAT5A | c.1888G>A p.A630T | Missense Mutation (SNP) | VAF 22/148 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV61806937; called by muse, mutect2, varscan2
- SULF1 | c.1029del p.F343Lfs*7 | Frame Shift Del (DEL) | VAF 13/84 reads (15%) | catalogued as rs773014665, COSV52672549; called by mutect2, pindel
- SULT2B1 | c.454G>A p.V152I (on ENST00000201586 / NM_177973.2; = p.V137I on NM_004605.2) | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.143); catalogued as rs1432402312; called by muse, mutect2, varscan2
- SV2A | c.577G>A p.A193T | Missense Mutation (SNP) | VAF 33/180 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as COSV64964981; called by muse, mutect2, varscan2
- SYNM | c.89G>T p.R30L | Missense Mutation (SNP) | VAF 79/366 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs113288259; called by muse, mutect2, varscan2
- SYT6 | c.152C>T p.A51V | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as COSV65773889; called by muse, mutect2, varscan2
- TAS2R19 | c.495G>T p.K165N | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.344); catalogued as rs985624326; called by muse, varscan2
- TBC1D25 | c.1120G>A p.A374T | Missense Mutation (SNP) | VAF 15/354 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.05); catalogued as COSV100952225; called by muse, mutect2
- TCF7L2 | c.1259G>A p.R420Q (on ENST00000355995 / NM_001367943.1; = p.R397Q on NM_030756.5) | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs867720073, COSV53338337; called by muse, mutect2
- TCHP | c.522del p.K174Nfs*26 | Frame Shift Del (DEL) | VAF 18/118 reads (15%) | catalogued as rs763438715; called by mutect2, varscan2
- TDRD6 | c.4558del p.M1520* | Frame Shift Del (DEL) | VAF 15/50 reads (30%) | catalogued as rs145334816, COSV60176047; called by mutect2, varscan2
- TESK2 | c.393+2T>C p.X131_splice | Splice Site (SNP) | VAF 7/63 reads (11%) | catalogued as COSV59155853; called by muse, mutect2, varscan2
- TESMIN | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 7/34 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.775); catalogued as COSV54834482; called by muse, mutect2, varscan2
- TLK2 | c.1006G>A p.E336K | Missense Mutation (SNP) | VAF 24/163 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV58305731; called by muse, mutect2, varscan2
- TLNRD1 | c.250G>A p.A84T | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.622); catalogued as rs1006324901, COSV51256996; called by muse, mutect2, varscan2
- TMCC1 | c.1130G>A p.R377Q (on ENST00000393238 / NM_001349268.2; = p.R53Q on NM_015008.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/144 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs12171319; called by muse, mutect2, varscan2
- TMEM62 | c.123dup p.R42Qfs*43 | Frame Shift Ins (INS) | VAF 27/144 reads (19%) | catalogued as rs1436262586; called by mutect2, pindel, varscan2
- TMEM63B | c.1589C>T p.P530L | Missense Mutation (SNP) | VAF 33/255 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52479139, COSV52479422; called by muse, mutect2, varscan2
- TMEM67 | c.425G>T p.G142V | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV60041931; called by muse, mutect2, varscan2
- TNK2 | c.2084G>A p.G695D | Missense Mutation (SNP) | VAF 45/235 reads (19%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.013); catalogued as rs1192168006; called by muse, mutect2, varscan2
- TNKS1BP1 | c.1151del p.P384Lfs*8 | Frame Shift Del (DEL) | VAF 11/52 reads (21%) | catalogued as rs751775914; called by mutect2, pindel, varscan2
- TNR | c.1183G>A p.V395I | Missense Mutation (SNP) | VAF 56/370 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.135); catalogued as rs1316869424, COSV54891795; called by muse, mutect2, varscan2
- TRAF7 | c.487G>A p.V163M | Missense Mutation (SNP) | VAF 53/385 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.636); catalogued as rs751318317, COSV58218349; called by muse, mutect2, varscan2
- TRIM39-RPP21 | c.1488_1489del p.Q496Hfs*6 | Frame Shift Del (DEL) | VAF 30/208 reads (14%) | catalogued as rs772327285; called by mutect2, pindel, varscan2
- TRIM58 | c.516+1G>A p.X172_splice | Splice Site (SNP) | VAF 9/128 reads (7%) | catalogued as COSV63571634, COSV99057540; called by muse, mutect2
- TRIM58 | c.551T>C p.L184S | Missense Mutation (SNP) | VAF 44/359 reads (12%) | SIFT tolerated (0.78); PolyPhen benign (0.003); catalogued as COSV100824934; called by muse, mutect2, varscan2
- TRPA1 | c.1512dup p.G505Rfs*7 | Frame Shift Ins (INS) | VAF 15/106 reads (14%) | catalogued as rs770577826; called by mutect2, varscan2
- TRPM1 | c.770del p.G257Afs*21 | Frame Shift Del (DEL) | VAF 38/344 reads (11%) | catalogued as rs760418372, COSV99855452; called by mutect2, pindel, varscan2
- TRRAP | c.6581A>G p.Q2194R (on ENST00000359863 / NM_001244580.1; = p.Q2176R on NM_003496.3) | Missense Mutation (SNP) | VAF 32/451 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs1386472809; called by muse, mutect2
- TUB | c.1215C>T p.N405= (on ENST00000299506 / NM_177972.3; = p.N460= on NM_003320.4) | Splice Region (SNP) | VAF 24/198 reads (12%) | catalogued as rs780890309; called by muse, mutect2, varscan2
- UBE3B | c.2710C>T p.R904C | Missense Mutation (SNP) | VAF 27/248 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs200182141; called by muse, varscan2
- UBQLN2 | c.1574dup p.G526Wfs*19 | Frame Shift Ins (INS) | VAF 40/188 reads (21%) | catalogued as rs757430527; called by mutect2, varscan2
- UGCG | c.1094del p.L365Cfs*9 | Frame Shift Del (DEL) | VAF 18/122 reads (15%) | catalogued as rs1243652090; called by mutect2, pindel, varscan2
- UGT1A7 | c.391del p.R131Efs*3 | Frame Shift Del (DEL) | VAF 34/148 reads (23%) | catalogued as rs66534818; called by mutect2, varscan2
- UNC80 | c.6583G>A p.G2195R | Missense Mutation (SNP) | VAF 29/124 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1469541777; called by muse, mutect2, varscan2
- UPF1 | c.2782C>T p.R928W (on ENST00000599848 / NM_001297549.2; = p.R917W on NM_002911.4) | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as rs1322079562; called by muse, mutect2, varscan2
- USH2A | c.11453C>A p.P3818H | Missense Mutation (SNP) | VAF 18/154 reads (12%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.964); catalogued as COSV56364424; called by muse, varscan2
- USP16 | c.1976G>A p.R659Q | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs570399715, COSV100537829, COSV57626506; called by muse, mutect2, varscan2
- UVSSA | c.2006G>A p.R669H | Missense Mutation (SNP) | VAF 17/164 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs758407459, COSV66229997; called by muse, mutect2, varscan2
- VCAN | c.1358C>A p.S453* | Nonsense Mutation (SNP) | VAF 43/205 reads (21%) | catalogued as COSV99424914; called by muse, mutect2, varscan2
- VCAN | c.9166G>A p.A3056T | Missense Mutation (SNP) | VAF 21/142 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs953528360; called by muse, mutect2, varscan2
- WBP1 | c.266G>A p.R89Q | Missense Mutation (SNP) | VAF 23/227 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs753151746; called by muse, mutect2, varscan2
- WDFY4 | c.7910C>T p.S2637L | Missense Mutation (SNP) | VAF 29/223 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1162001993, COSV55423649; called by muse, mutect2, varscan2
- WNT16 | c.500del p.G167Afs*17 (on ENST00000222462 / NM_057168.2; = p.G157Afs*17 on NM_016087.2) | Frame Shift Del (DEL) | VAF 68/389 reads (17%) | catalogued as rs771899177; called by mutect2, varscan2
- XYLT1 | c.1417G>A p.A473T | Missense Mutation (SNP) | VAF 20/181 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs1310366694, COSV54490999; called by muse, mutect2, varscan2
- YIPF7 | c.113C>G p.S38C | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV60657586; called by muse, mutect2, varscan2
- YY1 | c.422G>A p.G141D | Missense Mutation (SNP) | VAF 40/530 reads (8%) | SIFT tolerated (0.88); PolyPhen benign (0.116); catalogued as rs748178185, COSV51760822; called by muse, mutect2
- ZBTB24 | c.404del p.P135Qfs*6 | Frame Shift Del (DEL) | VAF 27/177 reads (15%) | catalogued as COSV57783189; called by mutect2, pindel, varscan2
- ZC3H3 | c.302del p.G101Afs*102 | Frame Shift Del (DEL) | VAF 33/277 reads (12%) | catalogued as rs760469533; called by mutect2, pindel, varscan2
- ZFHX2 | c.5770dup p.V1924Gfs*3 | Frame Shift Ins (INS) | VAF 34/197 reads (17%) | catalogued as rs748108531; called by mutect2, varscan2
- ZFYVE1 | c.1100C>A p.P367H | Missense Mutation (SNP) | VAF 22/127 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.27); catalogued as COSV100606616, COSV59611743; called by muse, mutect2, varscan2
- ZNF106 | c.1444del p.S482Pfs*33 | Frame Shift Del (DEL) | VAF 24/153 reads (16%) | catalogued as rs1198467282, COSV55516091; called by mutect2, varscan2
- ZNF385B | c.459del p.A154Rfs*50 | Frame Shift Del (DEL) | VAF 5/29 reads (17%) | catalogued as COSV61178677; called by mutect2, pindel
- ZNF420 | c.2045A>G p.H682R | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs775715557; called by muse, mutect2, varscan2
- ZNF556 | c.740G>A p.R247H | Missense Mutation (SNP) | VAF 40/237 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.467); catalogued as rs146297141, COSV56911178; called by muse, mutect2, varscan2
- ZNF557 | c.1185dup p.P396Tfs*3 (on ENST00000414706 / NM_001044388.2; = p.P403Tfs*3 on NM_024341.3 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 13/77 reads (17%) | catalogued as rs759839287; called by mutect2, varscan2
- ZNF665 | c.1066C>T p.R356* (on ENST00000600412; = p.R421* on NM_024733.5 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 16/98 reads (16%) | catalogued as rs1184573407, COSV67214599; called by muse, mutect2, varscan2
- ZNF665 | c.418C>T p.P140S (on ENST00000600412; = p.P205S on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.228); catalogued as rs747621123; called by muse, mutect2, varscan2
- ZSCAN29 | c.772G>A p.A258T | Missense Mutation (SNP) | VAF 30/162 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as rs753893132; called by muse, mutect2, varscan2
- ABCA7 | c.2373C>A p.D791E | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- ABCB1 | c.2557T>C p.Y853H | Missense Mutation (SNP) | VAF 23/164 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); called by muse, varscan2
- ABCB8 | c.1496del p.P499Lfs*33 (on ENST00000297504 / NM_001282291.2; = p.P482Lfs*33 on NM_007188.5) | Frame Shift Del (DEL) | VAF 44/233 reads (19%) | called by mutect2, pindel, varscan2
- ABL1 | c.436A>G p.N146D | Missense Mutation (SNP) | VAF 56/374 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.335); called by muse, mutect2, varscan2
- ACOT12 | c.41C>T p.A14V | Missense Mutation (SNP) | VAF 18/252 reads (7%) | SIFT tolerated (0.44); PolyPhen benign (0.028); called by muse, mutect2
- ACTR1B | c.500C>T p.A167V | Missense Mutation (SNP) | VAF 18/444 reads (4%) | SIFT tolerated (0.34); PolyPhen benign (0.02); called by muse, mutect2
- ACTR6 | c.782A>G p.Y261C | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.361); called by muse, mutect2, varscan2
- ADAM28 | c.516T>A p.D172E | Missense Mutation (SNP) | VAF 29/128 reads (23%) | SIFT tolerated (0.54); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- ADGRL1 | c.2981C>T p.A994V (on ENST00000340736 / NM_001008701.3; = p.A989V on NM_014921.5) | Missense Mutation (SNP) | VAF 46/211 reads (22%) | SIFT tolerated (0.46); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- AFAP1L1 | c.1447C>A p.L483M | Missense Mutation (SNP) | VAF 56/278 reads (20%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- AFP | c.843+1dup | Frame Shift Ins (INS) | VAF 26/191 reads (14%) | called by mutect2, pindel, varscan2
- AGBL5 | c.2437dup p.R813Pfs*7 | Frame Shift Ins (INS) | VAF 16/128 reads (13%) | called by mutect2, varscan2
- AKAP9 | c.6230del p.N2077Ifs*4 (on ENST00000359028; = p.N2045Ifs*4 on NM_005751.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 8/74 reads (11%) | called by mutect2, pindel
- ALG13 | c.995A>T p.Y332F | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ALKBH2 | c.83C>T p.A28V | Missense Mutation (SNP) | VAF 43/234 reads (18%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- AMPD2 | c.1698+1G>A p.X566_splice | Splice Site (SNP) | VAF 27/148 reads (18%) | called by muse, mutect2, varscan2
- ANKRD36C | c.200C>T p.T67I | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- ANKRD42 | c.261T>A p.N87K | Missense Mutation (SNP) | VAF 28/136 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.501); called by mutect2, varscan2
- AR | c.794G>T p.G265V | Missense Mutation (SNP) | VAF 7/113 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- ARHGAP5 | c.2805del p.F935Lfs*5 | Frame Shift Del (DEL) | VAF 6/35 reads (17%) | called by mutect2, pindel, varscan2
- ARID1B | c.89G>T p.S30I | Missense Mutation (SNP) | VAF 36/191 reads (19%) | SIFT deleterious, low confidence (0); called by muse, varscan2
- ARID1B | c.5508del p.L1837* | Frame Shift Del (DEL) | VAF 49/287 reads (17%) | called by mutect2, pindel, varscan2
- ASCC3 | c.3729del p.K1243Nfs*48 | Frame Shift Del (DEL) | VAF 8/42 reads (19%) | called by mutect2, pindel, varscan2
- BANK1 | c.1801del p.T601Lfs*8 | Frame Shift Del (DEL) | VAF 17/125 reads (14%) | called by mutect2, pindel, varscan2
- BCHE | c.1321G>T p.G441* | Nonsense Mutation (SNP) | VAF 24/151 reads (16%) | called by muse, mutect2, varscan2
- BCORL1 | c.3496del p.A1166Lfs*56 | Frame Shift Del (DEL) | VAF 13/103 reads (13%) | called by mutect2, pindel
- BEND3 | c.793del p.D265Tfs*54 | Frame Shift Del (DEL) | VAF 38/236 reads (16%) | called by mutect2, varscan2
- BICRAL | c.2396A>G p.N799S | Missense Mutation (SNP) | VAF 35/200 reads (18%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- BMPER | c.644T>A p.I215K | Missense Mutation (SNP) | VAF 50/329 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- BORA | c.163C>T p.H55Y | Missense Mutation (SNP) | VAF 7/137 reads (5%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); called by muse, mutect2
- BRWD3 | c.4181T>C p.V1394A | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.255); called by mutect2, varscan2
- BTN3A3 | c.1462C>T p.H488Y | Missense Mutation (SNP) | VAF 30/182 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- C18orf21 | c.32C>T p.A11V | Missense Mutation (SNP) | VAF 40/286 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- C1GALT1C1 | c.881A>G p.Y294C | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C9 | c.1431_1432del p.Y477* | Nonsense Mutation (DEL) | VAF 14/88 reads (16%) | called by pindel, varscan2
- CACNA1S | c.2943G>A p.M981I | Missense Mutation (SNP) | VAF 94/687 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CADM1 | c.989T>C p.V330A | Missense Mutation (SNP) | VAF 35/240 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- CBARP | c.1807C>T p.R603C | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CBX6 | c.923G>A p.R308H | Missense Mutation (SNP) | VAF 38/255 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- CDH10 | c.1920dup p.E641Rfs*18 | Frame Shift Ins (INS) | VAF 24/143 reads (17%) | called by mutect2, varscan2
- CDON | c.3670C>A p.L1224I | Missense Mutation (SNP) | VAF 11/112 reads (10%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- CDR2L | c.1079A>G p.Y360C | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- CDV3 | c.36_38del p.F13del | In Frame Del (DEL) | VAF 6/47 reads (13%) | called by pindel, varscan2
- CFAP47 | c.4648C>T p.P1550S | Missense Mutation (SNP) | VAF 17/138 reads (12%) | SIFT tolerated (0.72); PolyPhen benign (0.172); called by muse, mutect2, varscan2
- CFAP58 | c.191G>A p.C64Y | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CFAP77 | c.475A>C p.M159L | Missense Mutation (SNP) | VAF 41/250 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- CHD3 | c.5824del p.A1942Pfs*29 (on ENST00000330494 / NM_001005273.3; = p.A1908Pfs*29 on NM_005852.4) | Frame Shift Del (DEL) | VAF 43/262 reads (16%) | called by mutect2, pindel, varscan2
- CHD6 | c.5196del p.D1733Mfs*7 | Frame Shift Del (DEL) | VAF 17/106 reads (16%) | called by mutect2, pindel, varscan2
- CHERP | c.2410T>C p.S804P | Missense Mutation (SNP) | VAF 40/219 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- CHUK | c.1281G>A p.W427* | Nonsense Mutation (SNP) | VAF 36/235 reads (15%) | called by muse, mutect2, varscan2
- CKM | c.401G>A p.G134D | Missense Mutation (SNP) | VAF 22/364 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2
- CNTN4 | c.187A>T p.K63* | Nonsense Mutation (SNP) | VAF 6/76 reads (8%) | called by muse, mutect2
- CNTRL | c.311A>C p.N104T | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- COG7 | c.1806C>T p.S602= | Splice Region (SNP) | VAF 50/363 reads (14%) | called by muse, mutect2, varscan2
- COG7 | c.968A>T p.H323L | Missense Mutation (SNP) | VAF 27/175 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- COL11A1 | c.830A>G p.E277G | Missense Mutation (SNP) | VAF 47/217 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- COL18A1 | c.4681C>A p.L1561M (on ENST00000359759 / NM_130444.3; = p.L1326M on NM_030582.4) | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- COL6A3 | c.4757T>C p.I1586T | Missense Mutation (SNP) | VAF 39/218 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- CRB1 | c.3755G>A p.S1252N | Missense Mutation (SNP) | VAF 27/257 reads (11%) | SIFT tolerated (0.48); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- CREBBP | c.581G>A p.G194D | Missense Mutation (SNP) | VAF 56/594 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.914); called by muse, mutect2
- CRTC2 | c.1682A>G p.Q561R | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- CTTNBP2 | c.4280C>T p.A1427V | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- CYB5R4 | c.672G>T p.E224D | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- CYP2U1 | c.1201C>T p.P401S | Missense Mutation (SNP) | VAF 43/262 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DCAF4L2 | c.513G>A p.M171I | Missense Mutation (SNP) | VAF 56/352 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- DCHS2 | c.1009G>A p.A337T | Missense Mutation (SNP) | VAF 101/533 reads (19%) | SIFT tolerated (0.61); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- DEPDC5 | c.84A>T p.K28N | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DGKQ | c.1580C>T p.A527V | Missense Mutation (SNP) | VAF 20/168 reads (12%) | SIFT tolerated (0.47); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- DIP2A | c.1378del p.C460Vfs*25 | Frame Shift Del (DEL) | VAF 38/288 reads (13%) | called by mutect2, pindel, varscan2
- DMAP1 | c.241C>T p.R81C | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- DMD | c.10885C>T p.L3629F | Missense Mutation (SNP) | VAF 22/447 reads (5%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.637); called by muse, mutect2
- DMD | c.9510C>A p.N3170K | Missense Mutation (SNP) | VAF 68/406 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH11 | c.12423G>T p.E4141D | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- DNAJC25 | c.257G>A p.G86E | Missense Mutation (SNP) | VAF 38/237 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.38); called by muse, mutect2, varscan2
- DNM1 | c.1076del p.G359Efs*55 | Frame Shift Del (DEL) | VAF 33/166 reads (20%) | called by mutect2, pindel, varscan2
- DOCK9 | c.3220C>T p.H1074Y (on ENST00000376460 / NM_001366676.2; = p.H1075Y on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.498); called by muse, mutect2, varscan2
- DTX2 | c.448T>C p.Y150H | Missense Mutation (SNP) | VAF 81/549 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- DUOX2 | c.497G>A p.S166N | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- DVL2 | c.1745G>A p.S582N | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.024); called by muse, mutect2
- EBF2 | c.759del p.C254Afs*42 | Frame Shift Del (DEL) | VAF 19/98 reads (19%) | called by mutect2, pindel, varscan2
- ELAVL4 | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.735); called by muse, mutect2
- ENTPD7 | c.1060C>A p.P354T | Missense Mutation (SNP) | VAF 37/187 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- EPG5 | c.6478T>A p.S2160T | Missense Mutation (SNP) | VAF 12/210 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.794); called by muse, mutect2
- EPHX4 | c.949G>A p.V317I | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT tolerated (0.92); PolyPhen benign (0); called by muse, mutect2, varscan2
- EPRS1 | c.2989C>A p.L997I | Missense Mutation (SNP) | VAF 24/159 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- EPRS1 | c.1628C>A p.P543H | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- ESR2 | c.475T>C p.Y159H | Missense Mutation (SNP) | VAF 19/156 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FAT2 | c.5946G>T p.Q1982H | Missense Mutation (SNP) | VAF 21/298 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.273); called by muse, mutect2
- FAT4 | c.9025G>A p.A3009T | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.968); called by muse, mutect2
- FBXL17 | c.1021C>T p.R341C | Missense Mutation (SNP) | VAF 15/137 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FBXO31 | c.1455del p.V487Sfs*17 | Frame Shift Del (DEL) | VAF 35/270 reads (13%) | called by mutect2, pindel, varscan2
- FGF13 | c.68del p.P23Lfs*19 | Frame Shift Del (DEL) | VAF 6/57 reads (11%) | called by mutect2, pindel
- FLAD1 | c.569C>T p.A190V | Missense Mutation (SNP) | VAF 16/442 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- FLG2 | c.584A>T p.D195V | Missense Mutation (SNP) | VAF 33/175 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- FOXO1 | c.889G>A p.A297T | Missense Mutation (SNP) | VAF 29/199 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- FREM2 | c.3556A>G p.T1186A | Missense Mutation (SNP) | VAF 11/308 reads (4%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2
- FTCD | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 35/174 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, varscan2
- GATA5 | c.571A>G p.N191D | Missense Mutation (SNP) | VAF 53/286 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GHDC | c.823G>A p.A275T | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- GLIS2 | c.1190del p.G397Afs*127 | Frame Shift Del (DEL) | VAF 32/213 reads (15%) | called by mutect2, varscan2
- GLIS3 | c.870del p.A291Rfs*110 | Frame Shift Del (DEL) | VAF 9/52 reads (17%) | called by mutect2, pindel, varscan2
- GMCL2 | c.335T>A p.I112N | Missense Mutation (SNP) | VAF 17/144 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GON4L | c.3178dup p.V1060Gfs*5 | Frame Shift Ins (INS) | VAF 30/208 reads (14%) | called by mutect2, varscan2
- GPAM | c.1668dup p.I557Yfs*48 | Frame Shift Ins (INS) | VAF 46/249 reads (18%) | called by mutect2, pindel, varscan2
- GPATCH8 | c.3894G>T p.E1298D | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- GPR17 | c.292C>A p.L98M | Missense Mutation (SNP) | VAF 58/296 reads (20%) | SIFT tolerated (0.22); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GPRIN1 | c.2554C>T p.P852S | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.818); called by muse, mutect2, varscan2
- GRIN3B | c.2839G>A p.E947K | Missense Mutation (SNP) | VAF 28/160 reads (18%) | SIFT tolerated (0.73); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- GSTT2B | c.626C>T p.A209V | Missense Mutation (SNP) | VAF 87/479 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.531); called by muse, mutect2, varscan2
- GZF1 | c.287C>T p.T96I | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HDX | c.242C>G p.T81R | Missense Mutation (SNP) | VAF 9/111 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.143); called by muse, mutect2
- HEPHL1 | c.1688A>G p.K563R | Missense Mutation (SNP) | VAF 33/173 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- HERC2 | c.7021C>T p.Q2341* | Nonsense Mutation (SNP) | VAF 17/436 reads (4%) | called by muse, mutect2
- HIPK2 | c.3460C>T p.P1154S | Missense Mutation (SNP) | VAF 14/192 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); called by muse, mutect2
- HLA-DMA | c.198C>G p.D66E | Missense Mutation (SNP) | VAF 46/352 reads (13%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HNRNPH3 | c.65G>A p.G22E | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- HOXC8 | c.531del p.K177Nfs*12 | Frame Shift Del (DEL) | VAF 18/180 reads (10%) | called by mutect2, pindel
- ICOS | c.500del p.K167Rfs*17 | Frame Shift Del (DEL) | VAF 19/123 reads (15%) | called by mutect2, pindel, varscan2
- IGFBP4 | c.410G>A p.R137K | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGSF9 | c.680dup p.V228Sfs*24 | Frame Shift Ins (INS) | VAF 22/181 reads (12%) | called by mutect2, pindel, varscan2
- INAVA | c.1805G>A p.R602H | Missense Mutation (SNP) | VAF 44/375 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); called by muse, mutect2, varscan2
- INO80D | c.561A>T p.L187F | Missense Mutation (SNP) | VAF 9/119 reads (8%) | SIFT tolerated (0.51); PolyPhen benign (0.006); called by muse, mutect2
- INTS2 | c.1598C>T p.A533V | Missense Mutation (SNP) | VAF 29/154 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- IRS1 | c.3585C>G p.C1195W | Missense Mutation (SNP) | VAF 80/406 reads (20%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- ITCH | c.744del p.F248Lfs*58 (on ENST00000262650 / NM_001257137.3; = p.F207Lfs*58 on NM_031483.7 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 41/276 reads (15%) | called by mutect2, pindel, varscan2
- ITIH3 | c.1902C>A p.Y634* | Nonsense Mutation (SNP) | VAF 17/123 reads (14%) | called by muse, mutect2, varscan2
- JAK1 | c.2580del p.K860Nfs*16 | Frame Shift Del (DEL) | VAF 28/164 reads (17%) | called by mutect2, varscan2
- JAK1 | c.2187dup p.E730* | Frame Shift Ins (INS) | VAF 46/284 reads (16%) | called by mutect2, pindel, varscan2
- JCAD | c.1456del p.D486Mfs*44 | Frame Shift Del (DEL) | VAF 7/51 reads (14%) | called by mutect2, pindel, varscan2
- JUND | c.978_979del p.K327Sfs*96 | Frame Shift Del (DEL) | VAF 117/738 reads (16%) | called by mutect2, pindel, varscan2
- KATNIP | c.4573G>T p.V1525L | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- KCP | c.2896del p.E966Rfs*59 (on ENST00000620378; = p.E1026Rfs*59 on NM_001366122.1) | Frame Shift Del (DEL) | VAF 32/282 reads (11%) | called by mutect2, pindel, varscan2
- KCTD18 | c.110T>C p.M37T | Missense Mutation (SNP) | VAF 36/211 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KHDC1 | c.199T>C p.S67P | Missense Mutation (SNP) | VAF 11/208 reads (5%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.033); called by muse, mutect2
- KIAA1109 | c.12197G>A p.C4066Y | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- KIAA1217 | c.1399G>T p.G467C | Missense Mutation (SNP) | VAF 24/167 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIAA1586 | c.947T>C p.I316T | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- KLHL24 | c.487C>T p.L163F | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KLHL26 | c.368G>A p.S123N | Missense Mutation (SNP) | VAF 75/376 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- KLHL36 | c.1580C>T p.T527I | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- KLHL4 | c.1872del p.H625Mfs*32 | Frame Shift Del (DEL) | VAF 13/96 reads (14%) | called by mutect2, pindel, varscan2
- KMT2B | c.649del p.R217Gfs*22 | Frame Shift Del (DEL) | VAF 17/115 reads (15%) | called by mutect2, pindel, varscan2
- KPNB1 | c.1042G>A p.A348T | Missense Mutation (SNP) | VAF 42/268 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- KRT18 | c.82C>G p.P28A | Missense Mutation (SNP) | VAF 19/134 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.242); called by muse, mutect2, varscan2
- LAMA1 | c.848A>C p.E283A | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- LAMB3 | c.1243C>T p.P415S | Missense Mutation (SNP) | VAF 98/741 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LATS2 | c.3082C>T p.P1028S | Missense Mutation (SNP) | VAF 32/442 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0.006); called by muse, mutect2
- LAX1 | c.10G>A p.V4I | Missense Mutation (SNP) | VAF 42/312 reads (13%) | SIFT tolerated (0.77); PolyPhen benign (0); called by muse, mutect2, varscan2
- LGR6 | c.1427C>A p.A476D (on ENST00000367278 / NM_001017403.1; = p.A424D on NM_021636.3) | Missense Mutation (SNP) | VAF 38/225 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- LMOD2 | c.139C>A p.P47T | Missense Mutation (SNP) | VAF 74/395 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LOXL1 | c.801del p.D268Tfs*159 | Frame Shift Del (DEL) | VAF 28/167 reads (17%) | called by mutect2, pindel, varscan2
- LPAR3 | c.40del p.Y14Ifs*18 | Frame Shift Del (DEL) | VAF 10/46 reads (22%) | called by mutect2, pindel
- LRP12 | c.702del p.E235Nfs*3 | Frame Shift Del (DEL) | VAF 14/104 reads (13%) | called by mutect2, pindel, varscan2
- LRP8 | c.563G>A p.G188D | Missense Mutation (SNP) | VAF 78/480 reads (16%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.934); called by mutect2, varscan2
- LRRC37A3 | c.671C>T p.T224I | Missense Mutation (SNP) | VAF 10/546 reads (2%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.78); called by muse, mutect2
- LRRC73 | c.881-3_881-2del p.X294_splice | Splice Site (DEL) | VAF 24/214 reads (11%) | called by pindel, varscan2
- LTB4R | c.233T>G p.L78R | Missense Mutation (SNP) | VAF 29/178 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- LTBR | c.821_827del p.V274Efs*52 | Frame Shift Del (DEL) | VAF 21/110 reads (19%) | called by mutect2, pindel, varscan2
- LUC7L3 | c.746del p.K249Rfs*143 | Frame Shift Del (DEL) | VAF 12/66 reads (18%) | called by mutect2, pindel, varscan2
- MACF1 | c.18127_18135+11del p.X6043_splice (on ENST00000372915; = p.X4088_splice on NM_012090.5) | Splice Site (DEL) | VAF 12/80 reads (15%) | called by mutect2, pindel
- MALRD1 | c.2152G>T p.A718S | Missense Mutation (SNP) | VAF 21/148 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- MAP3K10 | c.2195A>G p.E732G | Missense Mutation (SNP) | VAF 18/138 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, varscan2
- MAP3K6 | c.3476C>A p.P1159H | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT tolerated (0.77); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- MAPK8IP1 | c.1002G>T p.E334D | Missense Mutation (SNP) | VAF 33/149 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- MARF1 | c.2640-1G>A p.X880_splice | Splice Site (SNP) | VAF 9/56 reads (16%) | called by muse, mutect2, varscan2
- MCM3AP | c.1001del p.G334Efs*19 | Frame Shift Del (DEL) | VAF 20/142 reads (14%) | called by mutect2, pindel, varscan2
- MDK | c.275del p.G92Vfs*16 | Frame Shift Del (DEL) | VAF 32/186 reads (17%) | called by pindel, varscan2
- MED10 | c.406T>C p.*136Qext*17 | Nonstop Mutation (SNP) | VAF 35/220 reads (16%) | called by muse, mutect2, varscan2
- MED13L | c.3413T>C p.M1138T | Missense Mutation (SNP) | VAF 49/265 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- MMRN1 | c.2121G>T p.Q707H | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- MPLKIP | c.26C>T p.P9L | Missense Mutation (SNP) | VAF 33/245 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- MRPL19 | c.97G>A p.A33T | Missense Mutation (SNP) | VAF 35/164 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MTMR4 | c.3307A>G p.K1103E | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.551); called by muse, mutect2, varscan2
- MUC4 | c.14422G>A p.A4808T (on ENST00000463781 / NM_018406.7; = p.A572T on NM_004532.6) | Missense Mutation (SNP) | VAF 22/292 reads (8%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.007); called by muse, mutect2
- MYDGF | c.86C>A p.A29E | Missense Mutation (SNP) | VAF 65/351 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- MYO9B | c.1099C>T p.H367Y | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- MZF1 | c.1019G>A p.G340D | Missense Mutation (SNP) | VAF 24/153 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NEURL2 | c.709_710del p.K237Efs*33 | Frame Shift Del (DEL) | VAF 50/368 reads (14%) | called by mutect2, pindel, varscan2
- NEURL4 | c.4087C>T p.R1363* | Nonsense Mutation (SNP) | VAF 46/222 reads (21%) | called by muse, mutect2, varscan2
- NF1 | c.3476G>T p.S1159I | Missense Mutation (SNP) | VAF 40/205 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- NFASC | c.494del p.P165Rfs*12 (on ENST00000339876 / NM_001378329.1; = p.P159Rfs*12 on NM_015090.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 35/350 reads (10%) | called by mutect2, pindel, varscan2
- NFATC1 | c.718A>T p.T240S | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.035); called by muse, mutect2
- NFATC2 | c.176C>T p.A59V | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- NOC2L | c.1111G>T p.G371C | Missense Mutation (SNP) | VAF 61/363 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- NOD1 | c.1865C>T p.A622V | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- NOTCH3 | c.1118G>A p.G373D | Missense Mutation (SNP) | VAF 93/535 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NUCB1 | c.713T>C p.L238P | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- NUP93 | c.1976A>G p.N659S | Missense Mutation (SNP) | VAF 52/262 reads (20%) | SIFT tolerated (0.74); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- NXPH3 | c.341T>C p.L114P | Missense Mutation (SNP) | VAF 19/387 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- ODF2L | c.1548G>T p.K516N (on ENST00000317336; = p.K500N on NM_020729.3) | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.208); called by muse, mutect2
- OLIG2 | c.653A>G p.H218R | Missense Mutation (SNP) | VAF 67/391 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- OPHN1 | c.128G>A p.G43D | Missense Mutation (SNP) | VAF 26/210 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OPN5 | c.641T>C p.V214A | Missense Mutation (SNP) | VAF 10/270 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.11); called by muse, mutect2
- OR13C2 | c.588G>T p.E196D | Missense Mutation (SNP) | VAF 25/159 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.405); called by muse, mutect2, varscan2
- OR2H1 | c.232del p.Q78Rfs*36 | Frame Shift Del (DEL) | VAF 22/145 reads (15%) | called by mutect2, pindel, varscan2
- OR4A16 | c.401T>C p.M134T | Missense Mutation (SNP) | VAF 13/223 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.824); called by muse, mutect2
- OR4K14 | c.223G>A p.A75T | Missense Mutation (SNP) | VAF 6/128 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.033); called by muse, mutect2
- PARP10 | c.869C>T p.A290V | Missense Mutation (SNP) | VAF 47/261 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PARP2 | c.1227G>T p.K409N | Missense Mutation (SNP) | VAF 39/184 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- PAX7 | c.1037C>T p.A346V | Missense Mutation (SNP) | VAF 27/492 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.893); called by muse, mutect2
- PBRM1 | c.4751del p.P1584Lfs*12 (on ENST00000296302 / NM_001366071.2; = p.P1477Lfs*12 on NM_018313.5) | Frame Shift Del (DEL) | VAF 4/17 reads (24%) | called by mutect2, pindel, varscan2
- PBX2 | c.1114-3C>T | Splice Region (SNP) | VAF 10/75 reads (13%) | called by muse, mutect2, varscan2
- PCDH12 | c.1264C>T p.Q422* | Nonsense Mutation (SNP) | VAF 35/225 reads (16%) | called by muse, mutect2, varscan2
- PCDHB6 | c.2360C>A p.S787Y | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- PDE4DIP | c.907G>T p.V303L | Missense Mutation (SNP) | VAF 15/143 reads (10%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.805); called by muse, mutect2, varscan2
- PEBP1 | c.319G>A p.V107M | Missense Mutation (SNP) | VAF 30/164 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- PFKFB1 | c.116C>T p.T39I | Missense Mutation (SNP) | VAF 6/133 reads (5%) | PolyPhen benign (0.285); called by muse, mutect2
- PKDREJ | c.6070A>G p.T2024A | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT tolerated (0.7); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PLAG1 | c.98dup p.N33Kfs*8 | Frame Shift Ins (INS) | VAF 13/99 reads (13%) | called by mutect2, pindel, varscan2
- PLEKHD1 | c.1498G>A p.A500T | Missense Mutation (SNP) | VAF 27/134 reads (20%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PLEKHG4 | c.2929G>A p.A977T | Missense Mutation (SNP) | VAF 71/438 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- PLIN1 | c.326del p.P109Lfs*8 | Frame Shift Del (DEL) | VAF 34/215 reads (16%) | called by mutect2, pindel, varscan2
- PLXNA1 | c.3051del p.Q1019Rfs*22 | Frame Shift Del (DEL) | VAF 27/182 reads (15%) | called by mutect2, pindel, varscan2
- PM20D2 | c.910A>T p.T304S | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.47); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- PMFBP1 | c.29G>T p.R10I | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- POP1 | c.2627G>A p.C876Y | Missense Mutation (SNP) | VAF 83/522 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- POU5F1B | c.566C>A p.A189D | Missense Mutation (SNP) | VAF 39/399 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.042); called by muse, mutect2
- PPP1R9B | c.2168T>G p.L723R | Missense Mutation (SNP) | VAF 65/349 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PPP4R3C | c.260C>A p.P87Q | Missense Mutation (SNP) | VAF 31/183 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.458); called by muse, mutect2, varscan2
- PRDM12 | c.785T>C p.M262T | Missense Mutation (SNP) | VAF 19/208 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); called by muse, mutect2
- PRDM13 | c.71T>C p.L24P | Missense Mutation (SNP) | VAF 22/219 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- PRICKLE2 | c.596C>T p.A199V (on ENST00000295902; = p.A143V on NM_198859.4) | Missense Mutation (SNP) | VAF 11/294 reads (4%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.874); called by muse, mutect2
- PROSER3 | c.631G>A p.A211T | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- PRR33 | c.431C>T p.A144V | Missense Mutation (SNP) | VAF 19/196 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2
- PRRC1 | c.1064T>C p.V355A | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- PRRC2A | c.6057del p.S2020Afs*36 | Frame Shift Del (DEL) | VAF 33/144 reads (23%) | called by mutect2, pindel, varscan2
- PSD3 | c.578dup p.N193Kfs*10 | Frame Shift Ins (INS) | VAF 22/122 reads (18%) | called by mutect2, varscan2
- PTGS1 | c.571del p.Q191Kfs*37 | Frame Shift Del (DEL) | VAF 37/229 reads (16%) | called by mutect2, pindel, varscan2
- PUM1 | c.3237C>T p.S1079= | Splice Region (SNP) | VAF 14/57 reads (25%) | called by muse, mutect2, varscan2
- QSER1 | c.1893del p.E632Kfs*8 (on ENST00000399302; = p.E761Kfs*8 on NM_001076786.3) | Frame Shift Del (DEL) | VAF 7/45 reads (16%) | called by mutect2, pindel, varscan2
- QTRT1 | c.1005C>A p.H335Q | Missense Mutation (SNP) | VAF 74/404 reads (18%) | SIFT tolerated (0.6); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- RAD54B | c.2660C>A p.P887H | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- RASGRP2 | c.522+1G>T p.X174_splice | Splice Site (SNP) | VAF 51/444 reads (11%) | called by muse, mutect2, varscan2
- RASGRP4 | c.1091C>T p.A364V | Missense Mutation (SNP) | VAF 48/341 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RBM45 | c.337C>T p.R113* | Nonsense Mutation (SNP) | VAF 4/38 reads (11%) | called by muse, mutect2
- RC3H2 | c.521A>G p.Q174R | Missense Mutation (SNP) | VAF 16/352 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.775); called by muse, mutect2
- RCN2 | c.386G>T p.R129L | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.598); called by muse, mutect2
- RFX2 | c.423del p.S142Afs*72 | Frame Shift Del (DEL) | VAF 29/173 reads (17%) | called by mutect2, pindel, varscan2
- RHBDF1 | c.2293C>T p.P765S | Missense Mutation (SNP) | VAF 40/297 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- RIBC2 | c.361del p.L121* | Frame Shift Del (DEL) | VAF 36/239 reads (15%) | called by mutect2, pindel, varscan2
- RICTOR | c.3992C>T p.A1331V | Missense Mutation (SNP) | VAF 21/145 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- RNF103 | c.824G>T p.S275I | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.22); called by muse, mutect2, varscan2
- RNF2 | c.235G>T p.A79S | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); called by muse, mutect2
- RUNX2 | c.650T>A p.I217N | Missense Mutation (SNP) | VAF 16/234 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- SAFB | c.2117G>T p.R706L | Missense Mutation (SNP) | VAF 59/214 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SALL1 | c.906C>G p.S302R | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.383); called by muse, mutect2, varscan2
- SCUBE2 | c.2603T>C p.I868T (on ENST00000649792 / NM_001367977.2; = p.I811T on NM_020974.3) | Missense Mutation (SNP) | VAF 9/267 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- SDHAF2 | c.355T>A p.Y119N | Missense Mutation (SNP) | VAF 34/174 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- SEL1L3 | c.391del p.R131Gfs*15 | Frame Shift Del (DEL) | VAF 16/110 reads (15%) | called by mutect2, varscan2
- SELENOV | c.244C>A p.P82T | Missense Mutation (SNP) | VAF 95/380 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- SERPINH1 | c.503G>A p.S168N | Missense Mutation (SNP) | VAF 68/379 reads (18%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- SERTAD3 | c.47A>G p.E16G | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.26); PolyPhen benign (0.006); called by muse, varscan2
- SETD1B | c.22del p.H8Tfs*27 | Frame Shift Del (DEL) | VAF 12/60 reads (20%) | called by mutect2, varscan2
- SETX | c.5243del p.F1748Sfs*3 | Frame Shift Del (DEL) | VAF 24/137 reads (18%) | called by mutect2, pindel, varscan2
- SH3BP4 | c.787T>A p.S263T | Missense Mutation (SNP) | VAF 50/301 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SH3PXD2A | c.1584del p.S529Afs*43 (on ENST00000369774 / NM_001365079.1; = p.S501Afs*43 on NM_014631.2) | Frame Shift Del (DEL) | VAF 11/76 reads (14%) | called by mutect2, pindel, varscan2
- SKIL | c.290G>C p.S97T | Missense Mutation (SNP) | VAF 29/158 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SLC12A5 | c.3232C>T p.R1078W (on ENST00000454036 / NM_001134771.2; = p.R1055W on NM_020708.5) | Missense Mutation (SNP) | VAF 39/236 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- SLC13A1 | c.1564T>A p.C522S | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated (0.9); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- SLC25A28 | c.215T>C p.V72A | Missense Mutation (SNP) | VAF 44/200 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.199); called by muse, mutect2, varscan2
- SLC2A2 | c.1225A>G p.S409G | Missense Mutation (SNP) | VAF 46/254 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- SLC4A2 | c.341del p.P114Rfs*131 | Frame Shift Del (DEL) | VAF 36/202 reads (18%) | called by mutect2, pindel, varscan2
- SLC5A5 | c.898G>T p.G300C | Missense Mutation (SNP) | VAF 103/513 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLCO3A1 | c.967del p.L323Wfs*13 | Frame Shift Del (DEL) | VAF 18/154 reads (12%) | called by mutect2, pindel, varscan2
- SLITRK6 | c.1907G>T p.R636M | Missense Mutation (SNP) | VAF 23/150 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- SMAD7 | c.626del p.P209Lfs*115 | Frame Shift Del (DEL) | VAF 8/54 reads (15%) | called by mutect2, varscan2
- SOX13 | c.299A>C p.E100A | Missense Mutation (SNP) | VAF 31/268 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- SP8 | c.940C>T p.P314S (on ENST00000361443 / NM_198956.4; = p.P332S on NM_182700.6) | Missense Mutation (SNP) | VAF 78/409 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SPATA4 | c.366del p.K122Nfs*8 | Frame Shift Del (DEL) | VAF 6/53 reads (11%) | called by mutect2, pindel, varscan2
- SPEF2 | c.3257C>T p.A1086V | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.115); called by muse, mutect2
- SPRR2F | c.149G>A p.C50Y | Missense Mutation (SNP) | VAF 21/191 reads (11%) | PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SPTBN1 | c.6885G>A p.M2295I | Missense Mutation (SNP) | VAF 38/215 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- SRSF3 | c.342-8G>T | Splice Region (SNP) | VAF 19/99 reads (19%) | called by muse, mutect2, varscan2
- SSBP2 | c.502C>T p.H168Y | Missense Mutation (SNP) | VAF 22/151 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.845); called by mutect2, varscan2
- SSX3 | c.548C>A p.P183H | Missense Mutation (SNP) | VAF 12/274 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- SSX7 | c.200T>C p.L67P | Missense Mutation (SNP) | VAF 14/244 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); called by muse, mutect2
- STARD8 | c.1333G>A p.V445M | Missense Mutation (SNP) | VAF 26/176 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- STARD9 | c.1738G>A p.A580T | Missense Mutation (SNP) | VAF 38/258 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SUFU | c.546C>A p.D182E | Missense Mutation (SNP) | VAF 52/318 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SYNE1 | c.23092C>T p.Q7698* (on ENST00000367255 / NM_182961.4; = p.Q7627* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 28/214 reads (13%) | called by muse, mutect2, varscan2
- SYT7 | c.1153A>G p.K385E | Missense Mutation (SNP) | VAF 22/152 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- TAF11 | c.280A>G p.K94E | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- TARDBP | c.1021G>A p.A341T | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.992); called by muse, mutect2
- TCEAL1 | c.14G>A p.R5H | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- TCERG1L | c.968del p.G323Efs*51 | Frame Shift Del (DEL) | VAF 16/113 reads (14%) | called by mutect2, varscan2
- TENM2 | c.3280dup p.L1094Pfs*5 (on ENST00000518659 / NM_001122679.2; = p.L862Pfs*5 on NM_001080428.3) | Frame Shift Ins (INS) | VAF 53/350 reads (15%) | called by mutect2, pindel, varscan2
- TEX10 | c.13del p.R5Efs*10 | Frame Shift Del (DEL) | VAF 9/35 reads (26%) | called by mutect2, pindel, varscan2
- THBS1 | c.1027-2A>G p.X343_splice | Splice Site (SNP) | VAF 9/168 reads (5%) | called by muse, mutect2
- TJP2 | c.1683G>T p.Q561H | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- TMEM151B | c.590G>A p.R197H | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TMEM185B | c.260C>A p.A87D | Missense Mutation (SNP) | VAF 12/204 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.88); called by muse, mutect2
- TMEM220 | c.401del p.F134Sfs*26 | Frame Shift Del (DEL) | VAF 12/76 reads (16%) | called by mutect2, pindel, varscan2
- TMUB1 | c.377G>A p.G126D | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- TNFAIP3 | c.1369C>T p.P457S | Missense Mutation (SNP) | VAF 38/225 reads (17%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- TRIO | c.4348A>G p.I1450V | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.129); called by muse, mutect2
- TTC30B | c.534dup p.A179Cfs*11 | Frame Shift Ins (INS) | VAF 51/287 reads (18%) | called by mutect2, pindel, varscan2
- TTI2 | c.835C>T p.P279S | Missense Mutation (SNP) | VAF 37/271 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TTLL2 | c.665T>A p.I222K | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TTYH3 | c.938G>A p.G313D | Missense Mutation (SNP) | VAF 28/162 reads (17%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- TUBB6 | c.454A>G p.I152V | Missense Mutation (SNP) | VAF 42/274 reads (15%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- TUBGCP3 | c.1276G>A p.V426I | Missense Mutation (SNP) | VAF 22/152 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- UBAP2L | c.2249T>C p.V750A | Missense Mutation (SNP) | VAF 13/218 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2
- ULK4 | c.917C>A p.S306Y | Missense Mutation (SNP) | VAF 28/137 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.312); called by muse, mutect2, varscan2
- UPF1 | c.3174G>T p.Q1058H (on ENST00000599848 / NM_001297549.2; = p.Q1047H on NM_002911.4) | Missense Mutation (SNP) | VAF 90/566 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- URB2 | c.1341del p.A448Pfs*29 | Frame Shift Del (DEL) | VAF 18/148 reads (12%) | called by mutect2, pindel, varscan2
- VANGL2 | c.488G>A p.S163N | Missense Mutation (SNP) | VAF 92/667 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.324); called by muse, mutect2, varscan2
- VSIG1 | c.517T>C p.Y173H | Missense Mutation (SNP) | VAF 11/213 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0.028); called by muse, mutect2
- WDFY4 | c.8675G>A p.R2892K | Missense Mutation (SNP) | VAF 12/243 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- WDR33 | c.1102G>A p.G368S | Missense Mutation (SNP) | VAF 30/162 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- WDR81 | c.2872G>A p.A958T | Missense Mutation (SNP) | VAF 49/311 reads (16%) | SIFT tolerated (0.73); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- WEE1 | c.725C>A p.S242Y | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- WNT3A | c.600C>A p.H200Q | Missense Mutation (SNP) | VAF 22/161 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- WRNIP1 | c.1753G>A p.A585T | Missense Mutation (SNP) | VAF 31/169 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- WWC3 | c.629C>A p.A210D | Missense Mutation (SNP) | VAF 8/196 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- XPNPEP1 | c.227C>A p.P76Q | Missense Mutation (SNP) | VAF 30/166 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); called by muse, mutect2, varscan2
- XPNPEP3 | c.1266del p.G423Afs*25 | Frame Shift Del (DEL) | VAF 65/470 reads (14%) | called by mutect2, pindel, varscan2
- ZBTB41 | c.1078del p.I360Yfs*14 | Frame Shift Del (DEL) | VAF 4/30 reads (13%) | called by pindel, varscan2
- ZFHX3 | c.5677_5678dup p.D1894Gfs*21 | Frame Shift Ins (INS) | VAF 32/258 reads (12%) | called by mutect2, varscan2
- ZFHX3 | c.2578G>T p.E860* | Nonsense Mutation (SNP) | VAF 28/200 reads (14%) | called by muse, mutect2, varscan2
- ZFP92 | c.1243C>A p.R415S | Missense Mutation (SNP) | VAF 8/160 reads (5%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); called by muse, mutect2
- ZFPM2 | c.527G>A p.S176N | Missense Mutation (SNP) | VAF 14/135 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZMYM2 | c.1325del p.N442Ifs*2 | Frame Shift Del (DEL) | VAF 17/81 reads (21%) | called by mutect2, pindel, varscan2
- ZNF107 | c.536A>G p.K179R | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- ZNF229 | c.1117G>T p.G373* | Nonsense Mutation (SNP) | VAF 24/160 reads (15%) | called by muse, mutect2, varscan2
- ZNF235 | c.1160G>A p.S387N | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZNF317 | c.1155G>A p.M385I | Missense Mutation (SNP) | VAF 68/316 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZNF444 | c.300del p.X100_splice | Splice Site (DEL) | VAF 12/75 reads (16%) | called by mutect2, pindel, varscan2
- ZNF473 | c.2476A>G p.S826G | Missense Mutation (SNP) | VAF 34/212 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- ZNF532 | c.1093del p.T365Pfs*13 | Frame Shift Del (DEL) | VAF 28/183 reads (15%) | called by mutect2, pindel, varscan2
- ZNF691 | c.586A>T p.K196* (on ENST00000372502; = p.K165* on NM_015911.3) | Nonsense Mutation (SNP) | VAF 38/250 reads (15%) | called by muse, mutect2, varscan2
- ZNF784 | c.937del p.E313Rfs*5 | Frame Shift Del (DEL) | VAF 22/193 reads (11%) | called by mutect2, pindel, varscan2
- ZNF843 | c.550G>A p.A184T | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF862 | c.2861C>T p.A954V | Missense Mutation (SNP) | VAF 28/237 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZYX | c.1393C>A p.P465T | Missense Mutation (SNP) | VAF 38/261 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- ZZEF1 | c.5759A>G p.D1920G | Missense Mutation (SNP) | VAF 40/584 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.291); called by muse, mutect2
- ABCB10 | c.141G>A p.R47= | Silent (SNP) | VAF 34/355 reads (10%) | called by muse, mutect2
- ABHD16B | c.969C>T p.D323= | Silent (SNP) | VAF 28/183 reads (15%) | called by muse, mutect2, varscan2
- AC138647.1 | c.234G>A p.L78= | Silent (SNP) | VAF 32/270 reads (12%) | catalogued as rs1563789025; called by muse, mutect2, varscan2
- ACTR1B | c.205C>T p.L69= | Silent (SNP) | VAF 27/141 reads (19%) | catalogued as rs1417374944; called by muse, mutect2, varscan2
- ACTR6 | c.1029A>G p.T343= | Silent (SNP) | VAF 10/69 reads (14%) | called by muse, mutect2, varscan2
- ADARB2 | c.2028G>A p.A676= | Silent (SNP) | VAF 27/144 reads (19%) | catalogued as rs369865323, COSV67181907; called by muse, mutect2, varscan2
- ADRM1 | c.708T>A p.A236= | Silent (SNP) | VAF 62/351 reads (18%) | called by muse, mutect2, varscan2
- AGK | c.126C>A p.A42= | Silent (SNP) | VAF 13/109 reads (12%) | called by muse, mutect2, varscan2
- AKAP7 | c.918C>T p.N306= (on ENST00000431975 / NM_016377.4; = p.N39= on NM_004842.4) | Silent (SNP) | VAF 11/112 reads (10%) | catalogued as rs377014445; called by muse, mutect2, varscan2
- AKNAD1 | c.2394T>G p.A798= | Silent (SNP) | VAF 12/53 reads (23%) | called by muse, mutect2, varscan2
- ALCAM | c.1176C>T p.C392= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as rs748308492, COSV60257271; called by mutect2, varscan2
- ANKFY1 | c.1683C>T p.V561= | Silent (SNP) | VAF 58/315 reads (18%) | called by muse, mutect2, varscan2
- ANKRD34A | c.1341G>A p.A447= | Silent (SNP) | VAF 27/164 reads (16%) | called by muse, mutect2, varscan2
- ARHGAP27 | c.1062G>A p.P354= (on ENST00000428638 / NM_001282290.1; = p.P13= on NM_199282.3) | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as rs1178123052, COSV100976670; called by muse, mutect2, varscan2
- ARHGEF33 | c.1683C>T p.A561= | Silent (SNP) | VAF 36/262 reads (14%) | called by muse, mutect2, varscan2
- ARVCF | c.2613C>T p.S871= | Silent (SNP) | VAF 9/67 reads (13%) | called by muse, mutect2, varscan2
- B3GAT1 | c.246G>T p.T82= | Silent (SNP) | VAF 41/207 reads (20%) | called by muse, mutect2, varscan2
- BAZ1B | c.441C>T p.A147= | Silent (SNP) | VAF 15/119 reads (13%) | called by muse, mutect2, varscan2
- BIRC2 | c.309T>C p.H103= | Silent (SNP) | VAF 15/88 reads (17%) | called by muse, mutect2, varscan2
- C2orf74 | c.372G>A p.K124= | Silent (SNP) | VAF 12/75 reads (16%) | called by muse, mutect2, varscan2
- CA14 | c.813G>A p.Q271= | Silent (SNP) | VAF 26/214 reads (12%) | called by muse, mutect2, varscan2
- CAGE1 | c.267A>G p.L89= | Silent (SNP) | VAF 8/34 reads (24%) | called by muse, mutect2, varscan2
- CAMK2D | c.93T>C p.C31= | Silent (SNP) | VAF 5/39 reads (13%) | called by muse, mutect2
- CAMTA1 | c.813C>T p.G271= | Silent (SNP) | VAF 3/10 reads (30%) | catalogued as COSV100346491; called by muse, mutect2
- CCDC130 | c.810C>T p.G270= | Silent (SNP) | VAF 32/136 reads (24%) | catalogued as COSV50005362; called by muse, mutect2, varscan2
- CCDC69 | c.105T>C p.G35= | Silent (SNP) | VAF 32/182 reads (18%) | called by muse, mutect2, varscan2
- CD5L | c.660T>C p.S220= | Silent (SNP) | VAF 41/234 reads (18%) | called by muse, mutect2, varscan2
- CEP112 | c.2242C>T p.L748= | Silent (SNP) | VAF 21/136 reads (15%) | called by muse, mutect2, varscan2
- CES1 | c.246G>A p.S82= | Silent (SNP) | VAF 73/748 reads (10%) | catalogued as rs1301602292; called by muse, mutect2
- CHIA | c.381G>A p.L127= (on ENST00000343320; = p.L19= on NM_021797.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 18/151 reads (12%) | called by muse, mutect2, varscan2
- CHM | c.171C>A p.S57= | Silent (SNP) | VAF 11/149 reads (7%) | called by muse, mutect2
- CNBP | c.315C>T p.G105= | Silent (SNP) | VAF 46/286 reads (16%) | catalogued as COSV69654958; called by muse, mutect2, varscan2
- COG7 | c.1947C>T p.D649= | Silent (SNP) | VAF 22/283 reads (8%) | catalogued as rs765301112; called by muse, mutect2
- CRHR1 | c.726G>A p.L242= (on ENST00000398285 / NM_001145146.2; = p.L213= on NM_004382.5) | Silent (SNP) | VAF 34/171 reads (20%) | catalogued as rs778224446; called by muse, mutect2, varscan2
- CSH1 | c.504C>A p.T168= | Silent (SNP) | VAF 16/544 reads (3%) | called by muse, mutect2
- CXCR6 | c.313C>T p.L105= | Silent (SNP) | VAF 48/321 reads (15%) | catalogued as rs1459046186; called by muse, mutect2, varscan2
- DCAF8L1 | c.1791C>T p.C597= | Silent (SNP) | VAF 6/24 reads (25%) | called by muse, mutect2, varscan2
- DELE1 | c.1302G>A p.G434= | Silent (SNP) | VAF 17/145 reads (12%) | called by muse, mutect2, varscan2
- DGCR8 | c.1641C>T p.T547= | Silent (SNP) | VAF 6/56 reads (11%) | called by muse, mutect2, varscan2
- DIP2A | c.3306G>A p.T1102= | Silent (SNP) | VAF 50/253 reads (20%) | catalogued as rs1014464391; called by muse, mutect2, varscan2
- DLGAP1 | c.1563C>T p.T521= | Silent (SNP) | VAF 23/200 reads (12%) | called by muse, mutect2, varscan2
- DNAH7 | c.6858C>T p.I2286= | Silent (SNP) | VAF 16/99 reads (16%) | catalogued as rs771896188, COSV100415626, COSV56765911; called by muse, mutect2, varscan2
- DND1 | c.504G>A p.A168= | Silent (SNP) | VAF 60/309 reads (19%) | catalogued as rs776126223; called by muse, mutect2, varscan2
- DPPA3 | c.18T>C p.F6= | Silent (SNP) | VAF 31/219 reads (14%) | called by muse, mutect2, varscan2
- EARS2 | c.753C>T p.L251= | Silent (SNP) | VAF 47/220 reads (21%) | catalogued as rs1042372629; called by muse, mutect2, varscan2
- ELANE | c.117C>T p.H39= | Silent (SNP) | VAF 40/224 reads (18%) | catalogued as COSV52255820; called by muse, varscan2
- ELAVL4 | c.126T>C p.D42= | Silent (SNP) | VAF 49/367 reads (13%) | called by muse, mutect2, varscan2
- ELFN1 | c.126C>T p.A42= | Silent (SNP) | VAF 19/354 reads (5%) | catalogued as rs1366696768; called by muse, mutect2
- ELMO1 | c.1002T>C p.A334= | Silent (SNP) | VAF 10/180 reads (6%) | catalogued as rs1045212275; called by muse, mutect2
- EMC1 | c.861C>A p.S287= | Silent (SNP) | VAF 8/115 reads (7%) | called by muse, mutect2
- EPHB3 | c.696C>A p.T232= | Silent (SNP) | VAF 34/174 reads (20%) | called by muse, mutect2, varscan2
- ERBB3 | c.1101C>T p.G367= | Silent (SNP) | VAF 40/209 reads (19%) | called by muse, mutect2, varscan2
- ERVMER34-1 | c.1257A>G p.A419= | Silent (SNP) | VAF 52/215 reads (24%) | called by muse, mutect2, varscan2
- ETV2 | c.783T>C p.R261= | Silent (SNP) | VAF 54/317 reads (17%) | catalogued as rs1249035089; called by muse, mutect2, varscan2
- FAM181A | c.945G>A p.A315= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as rs778855628; called by muse, mutect2
- FAM81B | c.1299T>C p.Y433= | Silent (SNP) | VAF 24/124 reads (19%) | catalogued as rs562119047; called by muse, mutect2, varscan2
- FARP1 | c.2418G>A p.P806= | Silent (SNP) | VAF 12/72 reads (17%) | catalogued as rs547676952; called by muse, mutect2
- FBH1 | c.822C>T p.D274= (on ENST00000362091 / NM_178150.3; = p.D325= on NM_032807.4) | Silent (SNP) | VAF 26/218 reads (12%) | catalogued as rs200323467; called by muse, mutect2, varscan2
- FFAR1 | c.384G>A p.A128= | Silent (SNP) | VAF 20/356 reads (6%) | catalogued as rs1234900277; called by muse, mutect2
- FIZ1 | c.618G>A p.A206= | Silent (SNP) | VAF 25/94 reads (27%) | catalogued as rs1005976017; called by muse, mutect2, varscan2
- FOXK1 | c.2079C>T p.S693= | Silent (SNP) | VAF 67/424 reads (16%) | catalogued as rs368673072; called by muse, mutect2, varscan2
- FZD9 | c.777C>G p.R259= | Silent (SNP) | VAF 37/206 reads (18%) | catalogued as COSV60671744; called by muse, mutect2, varscan2
- GADL1 | c.1441C>T p.L481= | Silent (SNP) | VAF 34/211 reads (16%) | called by muse, mutect2, varscan2
- GAK | c.2922C>A p.P974= | Silent (SNP) | VAF 24/200 reads (12%) | called by muse, mutect2, varscan2
- GDAP1 | c.720C>T p.C240= | Silent (SNP) | VAF 30/259 reads (12%) | catalogued as rs367790253; ClinVar: likely benign; called by muse, mutect2, varscan2
- GIGYF2 | c.757C>A p.R253= | Silent (SNP) | VAF 47/323 reads (15%) | catalogued as COSV101004110; called by muse, mutect2, varscan2
- GLI2 | c.2619G>T p.R873= (on ENST00000361492 / NM_001374353.1; = p.R890= on NM_005270.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/344 reads (5%) | called by muse, mutect2
- GPR158 | c.546G>A p.S182= | Silent (SNP) | VAF 38/199 reads (19%) | catalogued as rs142065649; called by muse, mutect2, varscan2
- GPR20 | c.873C>T p.C291= | Silent (SNP) | VAF 25/150 reads (17%) | called by muse, mutect2, varscan2
- GPR4 | c.222G>A p.V74= | Silent (SNP) | VAF 26/132 reads (20%) | called by muse, mutect2, varscan2
- GPT | c.816C>T p.D272= | Silent (SNP) | VAF 109/592 reads (18%) | called by muse, mutect2, varscan2
- GRAMD1B | c.303C>T p.L101= | Silent (SNP) | VAF 16/213 reads (8%) | called by muse, mutect2
- GRINA | c.948C>T p.G316= | Silent (SNP) | VAF 36/214 reads (17%) | catalogued as rs782198322; called by muse, mutect2, varscan2
- HMGXB3 | c.1818C>T p.G606= (on ENST00000613459; = p.G360= on NM_014983.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/70 reads (17%) | catalogued as rs895445101; called by muse, mutect2, varscan2
- HOXD1 | c.339G>A p.P113= | Silent (SNP) | VAF 12/91 reads (13%) | catalogued as rs1183450681; called by muse, mutect2, varscan2
- HSDL1 | c.567A>G p.L189= | Silent (SNP) | VAF 52/303 reads (17%) | catalogued as COSV99550236; called by muse, mutect2, varscan2
- HTRA4 | c.342C>A p.A114= | Silent (SNP) | VAF 9/142 reads (6%) | catalogued as rs1388928863; called by muse, mutect2
- IBSP | c.564C>T p.N188= | Silent (SNP) | VAF 19/194 reads (10%) | catalogued as rs747404256, COSV56894549; called by muse, mutect2, varscan2
- IGHMBP2 | c.1107C>T p.F369= | Silent (SNP) | VAF 55/339 reads (16%) | catalogued as rs137852670, CM042368, COSV54824123; called by muse, mutect2, varscan2
- IGKV3D-20 | c.75G>A p.T25= | Silent (SNP) | VAF 84/417 reads (20%) | catalogued as rs746244222; called by muse, mutect2, varscan2
- INSM2 | c.882T>C p.P294= | Silent (SNP) | VAF 31/133 reads (23%) | called by muse, mutect2, varscan2
- IVNS1ABP | c.570C>T p.S190= | Silent (SNP) | VAF 22/213 reads (10%) | called by muse, mutect2
- KAT6B | c.6222G>A p.*2074= | Silent (SNP) | VAF 72/430 reads (17%) | called by muse, mutect2, varscan2
- KCNK5 | c.1251C>T p.D417= | Silent (SNP) | VAF 67/360 reads (19%) | catalogued as rs138652901; called by muse, mutect2, varscan2
- KIF24 | c.4077C>T p.T1359= | Silent (SNP) | VAF 33/160 reads (21%) | catalogued as rs201157574, COSV99902850; called by muse, mutect2, varscan2
- KIF26B | c.5733G>A p.A1911= | Silent (SNP) | VAF 22/326 reads (7%) | catalogued as rs778365219; called by muse, mutect2
- KRT81 | c.999G>A p.T333= | Silent (SNP) | VAF 93/587 reads (16%) | catalogued as rs557990688, COSV59810310; called by muse, mutect2, varscan2
- LGALS3BP | c.447C>T p.S149= | Silent (SNP) | VAF 21/164 reads (13%) | called by muse, mutect2, varscan2
- LGI4 | c.261C>A p.S87= | Silent (SNP) | VAF 27/163 reads (17%) | catalogued as COSV59535025; called by muse, mutect2, varscan2
- LRRC37A3 | c.4551C>T p.L1517= | Silent (SNP) | VAF 89/510 reads (17%) | catalogued as rs1247647101; called by muse, mutect2, varscan2
- MAGEB4 | c.249C>T p.G83= | Silent (SNP) | VAF 16/80 reads (20%) | catalogued as rs770019939, COSV64396891; called by muse, mutect2, varscan2
- MAP1S | c.1035G>A p.A345= | Silent (SNP) | VAF 108/615 reads (18%) | catalogued as rs774416297; called by muse, mutect2, varscan2
- MAP3K4 | c.3381C>T p.G1127= | Silent (SNP) | VAF 15/83 reads (18%) | catalogued as rs757424021; called by muse, mutect2, varscan2
- MAPK8IP2 | c.1260C>T p.P420= | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as rs1266776416; called by muse, mutect2, varscan2
- MARCHF11 | c.429G>A p.S143= | Silent (SNP) | VAF 22/282 reads (8%) | catalogued as rs1380473251; called by muse, mutect2
- MEX3B | c.984G>A p.A328= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as COSV61663110; called by muse, mutect2, varscan2
- MFSD5 | c.744C>T p.R248= | Silent (SNP) | VAF 70/382 reads (18%) | catalogued as rs938781390; called by muse, mutect2
- MROH2B | c.2076G>A p.G692= | Silent (SNP) | VAF 16/108 reads (15%) | catalogued as rs754225587, COSV68188476; called by muse, mutect2, varscan2
- MRTFA | c.402G>A p.P134= | Silent (SNP) | VAF 29/194 reads (15%) | catalogued as rs1218052040, COSV62936720; called by muse, mutect2, varscan2
- MSC | c.177C>T p.C59= | Silent (SNP) | VAF 13/202 reads (6%) | called by muse, mutect2
- MST1R | c.393G>A p.A131= | Silent (SNP) | VAF 53/359 reads (15%) | catalogued as rs780104920; called by muse, mutect2, varscan2
- MTG2 | c.480C>T p.G160= | Silent (SNP) | VAF 39/216 reads (18%) | called by muse, mutect2, varscan2
- MTSS2 | c.1845C>T p.C615= | Silent (SNP) | VAF 74/468 reads (16%) | catalogued as rs767275878; called by muse, mutect2, varscan2
- MUC5AC | c.15915G>A p.T5305= | Silent (SNP) | VAF 59/330 reads (18%) | catalogued as rs760301277; called by muse, mutect2, varscan2
- MYH15 | c.3564A>C p.R1188= | Silent (SNP) | VAF 15/195 reads (8%) | called by muse, mutect2
- MYO9A | c.6855T>A p.R2285= | Silent (SNP) | VAF 23/173 reads (13%) | called by muse, mutect2, varscan2
- MYOG | c.249G>A p.R83= | Silent (SNP) | VAF 70/597 reads (12%) | called by muse, mutect2, varscan2
- NAIF1 | c.168C>T p.N56= | Silent (SNP) | VAF 32/241 reads (13%) | catalogued as rs1340661373; called by muse, mutect2, varscan2
- NAP1L4 | c.708C>A p.P236= | Silent (SNP) | VAF 7/114 reads (6%) | catalogued as COSV65882206; called by muse, mutect2
- NDUFB11 | c.144C>A p.P48= | Silent (SNP) | VAF 11/50 reads (22%) | called by muse, mutect2, varscan2
- NIPA1 | c.267G>A p.A89= | Silent (SNP) | VAF 52/329 reads (16%) | catalogued as rs751391752, COSV100508061; called by muse, mutect2, varscan2
- NKX1-1 | c.378G>A p.S126= | Silent (SNP) | VAF 24/93 reads (26%) | called by muse, mutect2, varscan2
- NPLOC4 | c.1782G>A p.Q594= | Silent (SNP) | VAF 35/249 reads (14%) | catalogued as COSV58617223; called by muse, mutect2, varscan2
- NPPB | c.333C>T p.G111= | Silent (SNP) | VAF 23/126 reads (18%) | called by muse, mutect2, varscan2
- ODF3 | c.573G>A p.R191= | Silent (SNP) | VAF 51/294 reads (17%) | called by muse, mutect2, varscan2
- OGFR | c.1464G>A p.S488= | Silent (SNP) | VAF 50/276 reads (18%) | catalogued as rs762442087; called by muse, mutect2, varscan2
- OIT3 | c.757C>T p.L253= | Silent (SNP) | VAF 19/148 reads (13%) | called by muse, mutect2, varscan2
- OR9G1 | c.720C>T p.C240= | Silent (SNP) | VAF 17/147 reads (12%) | catalogued as rs896979856; called by muse, mutect2, varscan2
- P3H4 | c.42C>T p.G14= | Silent (SNP) | VAF 10/244 reads (4%) | called by muse, mutect2
- PAX2 | c.414C>T p.I138= | Silent (SNP) | VAF 96/550 reads (17%) | called by muse, mutect2, varscan2
- PCDHA6 | c.534C>T p.F178= | Silent (SNP) | VAF 23/136 reads (17%) | catalogued as rs1202747267, COSV65357529; called by muse, mutect2, varscan2
- PCDHB12 | c.1902C>T p.D634= | Silent (SNP) | VAF 56/545 reads (10%) | called by muse, mutect2, varscan2
- PCDHGA6 | c.1554C>A p.R518= | Silent (SNP) | VAF 55/296 reads (19%) | called by muse, mutect2, varscan2
- PCNX2 | c.1347T>C p.N449= | Silent (SNP) | VAF 13/302 reads (4%) | called by muse, mutect2
- PGBD5 | c.882C>T p.C294= (on ENST00000525115; = p.C363= on NM_001258311.2) | Silent (SNP) | VAF 27/171 reads (16%) | catalogued as rs1353673493, COSV58410960; called by muse, mutect2, varscan2
- PHGDH | c.429G>A p.L143= | Silent (SNP) | VAF 26/530 reads (5%) | catalogued as rs1417980204; called by muse, mutect2
- PI4KA | c.1278T>C p.N426= | Silent (SNP) | VAF 19/160 reads (12%) | called by muse, mutect2, varscan2
- PKD1 | c.8670C>T p.S2890= | Silent (SNP) | VAF 120/797 reads (15%) | catalogued as rs1567176872, COSV99032328; called by muse, mutect2, varscan2
- PKMYT1 | c.513G>T p.V171= | Silent (SNP) | VAF 44/298 reads (15%) | called by muse, mutect2, varscan2
- PLEC | c.13248C>A p.P4416= (on ENST00000322810 / NM_201380.4; = p.P4306= on NM_000445.5) | Silent (SNP) | VAF 22/181 reads (12%) | called by muse, mutect2, varscan2
- PLXNA1 | c.3721C>T p.L1241= | Silent (SNP) | VAF 9/215 reads (4%) | called by muse, mutect2
- POLM | c.990C>T p.D330= | Silent (SNP) | VAF 33/168 reads (20%) | catalogued as rs766734385, COSV54241484; called by muse, mutect2, varscan2
- PPP1R3G | c.648G>A p.Q216= | Silent (SNP) | VAF 45/245 reads (18%) | called by muse, mutect2, varscan2
- PPP6R2 | c.1788G>A p.P596= (on ENST00000216061 / NM_001365836.1; = p.P569= on NM_014678.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 43/237 reads (18%) | catalogued as rs745576705; called by muse, mutect2, varscan2
165 further variants in this file (0 protein-altering or splice-affecting, 63 silent, 102 other) are not listed here.
